Somatic mutation profile of tumor specimen TCGA-CD-A4MI-01A (aliquot TCGA-CD-A4MI-01A-21D-A25D-08) from TCGA case TCGA-CD-A4MI, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIA; Tumor grade: G1; Age at diagnosis: 62.2 years (22,721 days).
Specimen TCGA-CD-A4MI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee3eb85d-a5b7-4108-ab4b-e658929ebff4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CD-A4MI-10A (Blood Derived Normal), aliquot TCGA-CD-A4MI-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f5676d0e-2dca-475c-8d36-7ddefeef7a6d

The open-access MAF lists 1,190 somatic variants for this specimen: 919 protein-altering or splice-affecting, 249 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 623, Silent 249, Frame Shift Del 196, Frame Shift Ins 41, Nonsense Mutation 33, Splice Site 12, Intron 10, Splice Region 7, In Frame Del 6, 5'Flank 4, RNA 3, 5'UTR 2.

Variants (750 of 1,190; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.5012del p.N1671Ifs*4 (on ENST00000272895 / NM_173076.3; = p.N1353Ifs*4 on NM_015657.3) | Frame Shift Del (DEL) | VAF 6/41 reads (15%) | catalogued as rs387906285, CD051281; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AR | c.1805G>A p.C602Y | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1555990470, CM103683, CM940086, COSV65953100; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- B2M | c.35T>A p.L12Q | Missense Mutation (SNP) | VAF 10/89 reads (11%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV62562913, COSV62563197; called by muse, varscan2
- DUSP16 | c.1447C>T p.R483* | Nonsense Mutation (SNP) | VAF 24/145 reads (17%) | hotspot (GDC flag); catalogued as COSV53806110; called by muse, mutect2, varscan2
- GJA1 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 23/171 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs750294638, CM030465, COSV56997002; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- KMT2B | c.521dup p.T176Dfs*8 | Frame Shift Ins (INS) | VAF 22/105 reads (21%) | catalogued as rs763183959; ClinVar: pathogenic; called by mutect2, varscan2
- KMT2D | c.1966del p.L656Cfs*274 | Frame Shift Del (DEL) | VAF 11/84 reads (13%) | catalogued as rs886042284; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MOGS | c.1801C>T p.R601* | Nonsense Mutation (SNP) | VAF 11/134 reads (8%) | catalogued as rs1057520537, COSV51968127; ClinVar: pathogenic; called by muse, mutect2
- MYO7A | c.1623dup p.K542Qfs*5 | Frame Shift Ins (INS) | VAF 26/213 reads (12%) | catalogued as rs782077721; ClinVar: pathogenic; called by mutect2, varscan2
- NCSTN | c.17del p.G6Vfs*22 | Frame Shift Del (DEL) | VAF 6/33 reads (18%) | catalogued as rs1266104510; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIGO | c.2361del p.T788Lfs*25 | Frame Shift Del (DEL) | VAF 15/137 reads (11%) | catalogued as rs770591449, COSV99956719; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- SLC17A5 | c.349del p.Y117Mfs*17 | Frame Shift Del (DEL) | VAF 22/206 reads (11%) | catalogued as rs772039085; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- STAT5B | c.1102del p.Q368Rfs*2 | Frame Shift Del (DEL) | VAF 12/52 reads (23%) | catalogued as rs761761205; ClinVar: pathogenic; called by mutect2, varscan2
- TTN | c.50737C>T p.R16913* (on ENST00000591111; = p.R9489* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 9/62 reads (15%) | catalogued as rs1483931960, COSV59888643; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AACS | c.796G>T p.G266C | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as COSV55534479; called by muse, mutect2, varscan2
- AASS | c.2688G>T p.M896I | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV62788865; called by muse, mutect2, varscan2
- ABCA10 | c.2732C>T p.T911M | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs747318337, COSV52218275; called by muse, mutect2, varscan2
- ABCA12 | c.3307A>G p.M1103V (on ENST00000272895 / NM_173076.3; = p.M785V on NM_015657.3) | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as COSV55949332; called by muse, mutect2, varscan2
- ABCA2 | c.5836G>A p.G1946S (on ENST00000614293; = p.G1916S on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs544639972, COSV55797467; called by muse, mutect2, varscan2
- ABCA3 | c.4387C>T p.Q1463* | Nonsense Mutation (SNP) | VAF 15/97 reads (15%) | catalogued as COSV57049510; called by muse, mutect2, varscan2
- ABCB4 | c.3342G>A p.W1114* (on ENST00000265723 / NM_018849.3; = p.W1107* on NM_000443.4) | Nonsense Mutation (SNP) | VAF 13/114 reads (11%) | catalogued as COSV55931986; called by muse, mutect2, varscan2
- ABCC9 | c.3937A>G p.K1313E | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.011); catalogued as COSV53962645; called by muse, mutect2, varscan2
- ABCC9 | c.667C>A p.L223M | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.624); catalogued as COSV53962657, COSV53983715; called by muse, mutect2, varscan2
- ABCG4 | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 40/237 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56642042; called by muse, mutect2, varscan2
- ABLIM1 | c.1019C>T p.T340M | Missense Mutation (SNP) | VAF 45/274 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.508); catalogued as rs1322528617, COSV53299667; called by muse, mutect2, varscan2
- AC132217.2 | c.64T>C p.S22P | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV56097119; called by muse, mutect2, varscan2
- ACAP3 | c.2096C>T p.A699V | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV57639883; called by muse, mutect2
- ACOX2 | c.1230G>T p.R410S | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.184); catalogued as COSV57147594, COSV57147646; called by muse, mutect2, varscan2
- ACSS2 | c.1372C>T p.R458C | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs373930264, COSV53622576; called by muse, mutect2, varscan2
- ACTA2 | c.64G>A p.G22S | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.835); catalogued as rs756496192, CM156144, COSV56515660; called by muse, mutect2, varscan2
- ACVR2A | c.285del p.D96Tfs*54 | Frame Shift Del (DEL) | VAF 14/122 reads (11%) | catalogued as rs1312707585, COSV54026507; called by mutect2, varscan2
- ADAM33 | c.1424G>A p.C475Y | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV62933633; called by muse, mutect2, varscan2
- ADAMDEC1 | c.1022del p.K341Rfs*7 | Frame Shift Del (DEL) | VAF 7/24 reads (29%) | catalogued as rs746174250; called by mutect2, varscan2
- ADAMTS1 | c.2486G>A p.G829D | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV53168688; called by muse, mutect2, varscan2
- ADAMTS19 | c.3347G>A p.R1116H | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs761846748, COSV99176829, COSV99179180; called by muse, mutect2, varscan2
- ADAMTS8 | c.1618C>T p.R540W | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757519748, COSV57291181; called by muse, mutect2, varscan2
- ADCY2 | c.1778G>A p.R593Q | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762541068, COSV100602528, COSV57859067; called by muse, mutect2, varscan2
- ADCY4 | c.1606A>G p.T536A | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.69); PolyPhen benign (0.166); catalogued as rs757204496, COSV60251960; called by muse, varscan2
- ADCY5 | c.3133C>T p.P1045S | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59194147; called by muse, mutect2, varscan2
- ADCY6 | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV57166231; called by muse, mutect2
- ADGRB1 | c.3521C>T p.S1174L | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60091842; called by muse, mutect2
- ADGRL3 | c.331C>A p.L111I (on ENST00000506720 / NM_001322402.2; = p.L43I on NM_015236.6) | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV72265739; called by muse, mutect2
- ADIPOR1 | c.577G>A p.V193I | Missense Mutation (SNP) | VAF 21/152 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.103); catalogued as rs996793166, COSV61850770; called by muse, mutect2, varscan2
- ADNP | c.2716G>A p.D906N | Missense Mutation (SNP) | VAF 30/210 reads (14%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs767970856, COSV62424468; called by muse, varscan2
- AFP | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1417717133, COSV56923903, COSV56924170; called by muse, mutect2, varscan2
- AGO1 | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as COSV64594678; called by muse, mutect2
- AHNAK | c.15769G>A p.A5257T | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.718); catalogued as COSV57203620; called by muse, mutect2
- AHNAK | c.1901C>A p.P634H | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57203631, COSV57219332; called by muse, mutect2, varscan2
- AHNAK2 | c.5564C>T p.A1855V | Missense Mutation (SNP) | VAF 52/398 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.061); catalogued as COSV60907903; called by muse, mutect2, varscan2
- AKAP7 | c.236del p.K79Rfs*21 | Frame Shift Del (DEL) | VAF 14/68 reads (21%) | catalogued as rs763109484, COSV100818792; called by mutect2, varscan2
- AKR7A2 | c.890G>A p.R297Q | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.605); catalogued as rs199970984, COSV52515602, COSV99352123; called by muse, mutect2, varscan2
- ALG10 | c.329T>C p.L110S | Missense Mutation (SNP) | VAF 20/173 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV56791665; called by muse, mutect2, varscan2
- ALMS1 | c.1561G>A p.A521T | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.009); catalogued as COSV52502818; called by muse, mutect2, varscan2
- ALOX15 | c.1161+2T>C p.X387_splice | Splice Site (SNP) | VAF 10/57 reads (18%) | catalogued as COSV53396142; called by muse, mutect2, varscan2
- AMBRA1 | c.2236A>G p.M746V (on ENST00000458649 / NM_001367468.1; = p.M656V on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as rs1414689971, COSV54048524; called by muse, mutect2, varscan2
- AMMECR1L | c.56G>A p.C19Y | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV55759994; called by muse, mutect2, varscan2
- AMPD2 | c.2350A>G p.I784V | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.169); catalogued as COSV56646191; called by muse, mutect2
- AMY2B | c.263C>A p.S88Y | Missense Mutation (SNP) | VAF 24/215 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100796240; called by muse, mutect2, varscan2
- ANKFY1 | c.64A>G p.K22E | Missense Mutation (SNP) | VAF 31/232 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV58914563; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.3730C>A p.L1244M | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51840593; called by muse, mutect2
- ANKRD30A | c.2664G>T p.K888N (on ENST00000611781; = p.K832N on NM_052997.2) | Missense Mutation (SNP) | VAF 14/163 reads (9%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs766046581, COSV64603887; called by muse, mutect2
- ANO2 | c.584A>G p.E195G (on ENST00000356134 / NM_001278597.3; = p.E199G on NM_001278596.3) | Missense Mutation (SNP) | VAF 30/341 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV59007939; called by muse, mutect2
- ANO3 | c.2674G>T p.G892C | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.928); catalogued as COSV56780731; called by muse, mutect2, varscan2
- ANXA11 | c.628C>T p.R210W | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768664021, COSV99626953; called by muse, mutect2, varscan2
- AP2A2 | c.170del p.K57Sfs*24 | Frame Shift Del (DEL) | VAF 38/180 reads (21%) | catalogued as rs753029866; called by mutect2, varscan2
- APOBEC3D | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1470578854, COSV53325587, COSV99329194; called by muse, mutect2, varscan2
- APPL2 | c.543C>A p.Y181* | Nonsense Mutation (SNP) | VAF 17/116 reads (15%) | catalogued as COSV51588148; called by muse, mutect2, varscan2
- AQP10 | c.239A>G p.H80R | Missense Mutation (SNP) | VAF 9/145 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61474420; called by muse, mutect2
- ARAP3 | c.1868C>A p.A623D | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53348611; called by muse, mutect2, varscan2
- ARHGAP32 | c.23G>A p.S8N | Missense Mutation (SNP) | VAF 26/225 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV59843262; called by muse, mutect2, varscan2
- ARHGAP33 | c.3094C>A p.P1032T | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); catalogued as COSV50119388; called by muse, mutect2, varscan2
- ARHGDIA | c.598_600del p.K200del | In Frame Del (DEL) | VAF 8/76 reads (11%) | catalogued as rs749862467; called by pindel, varscan2
- ARHGEF10L | c.2380G>T p.A794S | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.83); PolyPhen benign (0.007); catalogued as COSV51427670; called by muse, mutect2, varscan2
- ARHGEF15 | c.2440G>A p.E814K | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs534121147, COSV62724325, COSV62725188; called by muse, mutect2, varscan2
- ARNT2 | c.1335G>T p.Q445H | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.104); catalogued as COSV57581756; called by muse, mutect2, varscan2
- ASH1L | c.8698del p.T2900Qfs*44 (on ENST00000368346 / NM_001366177.2; = p.T2895Qfs*44 on NM_018489.3) | Frame Shift Del (DEL) | VAF 18/143 reads (13%) | catalogued as rs761154268; called by mutect2, varscan2
- ATM | c.610G>T p.G204* | Nonsense Mutation (SNP) | VAF 6/57 reads (11%) | catalogued as rs147915571, CM056524, COSV53726226, COSV99069705; called by muse, mutect2, varscan2
- ATP10A | c.2261G>T p.R754L | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63513572, COSV63516320; called by muse, mutect2, varscan2
- ATP11A | c.1992-1G>T p.X664_splice | Splice Site (SNP) | VAF 13/86 reads (15%) | catalogued as COSV52106160; called by muse, mutect2, varscan2
- ATP2B1 | c.3286G>T p.A1096S | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.182); catalogued as COSV53803848, COSV99666289; called by muse, mutect2, varscan2
- ATP6V1A | c.361G>T p.G121* | Nonsense Mutation (SNP) | VAF 19/126 reads (15%) | catalogued as COSV56360961, COSV56362916; called by muse, mutect2, varscan2
- ATXN1 | c.37C>T p.P13S | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55208399; called by muse, mutect2, varscan2
- ATXN2L | c.2997del p.Q1002Kfs*50 | Frame Shift Del (DEL) | VAF 14/138 reads (10%) | catalogued as rs1288664341; called by mutect2, pindel, varscan2
- AUH | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs548411527, COSV57861522; called by mutect2, varscan2
- AUTS2 | c.361C>A p.L121M | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV61383283; called by muse, mutect2, varscan2
- AUTS2 | c.543C>A p.S181R | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.59); catalogued as COSV61383286; called by muse, mutect2, varscan2
- AUTS2 | c.3272G>C p.G1091A | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as COSV61383294; called by muse, mutect2
- B2M | c.45_48del p.S16Afs*27 | Frame Shift Del (DEL) | VAF 11/81 reads (14%) | catalogued as COSV62562863; called by pindel, varscan2
- B3GALNT1 | c.314del p.K105Sfs*14 | Frame Shift Del (DEL) | VAF 18/135 reads (13%) | catalogued as rs759975633; called by mutect2, pindel, varscan2
- B3GNT4 | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 36/302 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs766622097, COSV57335713; called by muse, mutect2, varscan2
- B4GALT3 | c.377C>T p.A126V | Missense Mutation (SNP) | VAF 20/187 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60526436; called by muse, mutect2, varscan2
- BAHD1 | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs140194867; called by muse, mutect2, varscan2
- BBS4 | c.277T>C p.C93R | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV51436453; called by muse, mutect2, varscan2
- BCL7C | c.358del p.Q120Sfs*33 | Frame Shift Del (DEL) | VAF 14/99 reads (14%) | catalogued as rs758526156; called by mutect2, varscan2
- BCL9L | c.1448del p.P483Rfs*19 | Frame Shift Del (DEL) | VAF 30/207 reads (14%) | catalogued as rs752970264; called by mutect2, varscan2
- BICC1 | c.68G>A p.S23N | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.264); catalogued as COSV65856155, COSV65862677; called by muse, mutect2
- BRD1 | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.257); catalogued as COSV53454785; called by muse, mutect2, varscan2
- BRIP1 | c.1073T>C p.L358P | Missense Mutation (SNP) | VAF 27/224 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51993803; called by muse, mutect2, varscan2
- BRSK1 | c.1889C>T p.S630L | Missense Mutation (SNP) | VAF 32/312 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV58664618, COSV58667729; called by muse, mutect2, varscan2
- BRWD3 | c.1807C>T p.R603W | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866864028, COSV64743939; called by muse, mutect2, varscan2
- BTBD7 | c.173del p.K58Rfs*44 | Frame Shift Del (DEL) | VAF 20/184 reads (11%) | catalogued as rs752512017; called by mutect2, varscan2
- C9orf135 | c.33G>A p.W11* | Nonsense Mutation (SNP) | VAF 9/60 reads (15%) | catalogued as COSV65874543; called by muse, mutect2, varscan2
- CA7 | c.584C>T p.T195I | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58155992; called by muse, mutect2, varscan2
- CABLES1 | c.1523A>G p.H508R (on ENST00000256925 / NM_001100619.2; = p.H243R on NM_138375.2) | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV56930661; called by muse, mutect2, varscan2
- CAMK2A | c.1415C>T p.A472V (on ENST00000348628 / NM_171825.2; = p.A483V on NM_015981.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.628); catalogued as rs767783317, COSV62245066; called by muse, mutect2, varscan2
- CAMLG | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.006); catalogued as rs757373789, COSV51804251; called by muse, mutect2, varscan2
- CAMSAP1 | c.1625T>G p.L542R | Missense Mutation (SNP) | VAF 39/344 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1255434203, COSV56718396; called by muse, mutect2, varscan2
- CAMTA1 | c.3419C>A p.P1140H | Missense Mutation (SNP) | VAF 22/166 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57882163; called by muse, mutect2, varscan2
- CAPN5 | c.788G>C p.S263T (on ENST00000456580; = p.S223T on NM_004055.5) | Missense Mutation (SNP) | VAF 36/336 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.014); catalogued as COSV53685645; called by muse, mutect2, varscan2
- CAPNS2 | c.612G>A p.M204I | Missense Mutation (SNP) | VAF 45/297 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0.019); catalogued as COSV50894194; called by muse, mutect2, varscan2
- CARS1 | c.2153A>G p.K718R | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.167); catalogued as rs143403960; called by muse, mutect2, varscan2
- CASP4 | c.231del p.F77Lfs*3 | Frame Shift Del (DEL) | VAF 17/122 reads (14%) | catalogued as rs779092072; called by mutect2, pindel, varscan2
- CASP8 | c.281G>A p.G94D | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as COSV51845306; called by muse, mutect2
- CAVIN2 | c.1024C>T p.L342F | Missense Mutation (SNP) | VAF 21/202 reads (10%) | SIFT tolerated (0.7); PolyPhen benign (0.026); catalogued as COSV58423218; called by muse, mutect2, varscan2
- CCAR2 | c.1444G>A p.A482T | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs748696165, COSV52383125; called by muse, mutect2, varscan2
- CCDC106 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58273357; called by muse, mutect2, varscan2
- CCDC157 | c.1000C>T p.Q334* | Nonsense Mutation (SNP) | VAF 6/23 reads (26%) | catalogued as COSV57837526; called by muse, mutect2, varscan2
- CCDC18 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV58141278; called by muse, mutect2, varscan2
- CCDC3 | c.798dup p.Y267Lfs*25 | Frame Shift Ins (INS) | VAF 10/60 reads (17%) | catalogued as rs750606155; called by mutect2, varscan2
- CCDC33 | c.1678G>T p.V560L | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.352); catalogued as COSV51498630; called by muse, mutect2, varscan2
- CCDC97 | c.334C>T p.R112C | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as rs142783394, COSV54189903; called by muse, mutect2, varscan2
- CCL1 | c.188+1G>A p.X63_splice | Splice Site (SNP) | VAF 25/232 reads (11%) | catalogued as COSV56774333; called by muse, mutect2, varscan2
- CCR3 | c.823C>T p.R275W | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.901); catalogued as rs41276535, COSV62461650; called by muse, mutect2, varscan2
- CD320 | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs370038440; called by muse, mutect2, varscan2
- CD4 | c.809C>A p.P270H | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.941); catalogued as COSV50589103; called by muse, mutect2, varscan2
- CDR2 | c.646C>T p.R216W | Missense Mutation (SNP) | VAF 27/255 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.984); catalogued as rs760182484, COSV51675221; called by muse, mutect2, varscan2
- CELSR1 | c.7462G>A p.V2488I | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.053); catalogued as rs199555924; called by muse, mutect2, varscan2
- CELSR3 | c.1345G>T p.G449C | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50840005; called by muse, mutect2, varscan2
- CENPF | c.2144A>G p.Q715R | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV65272680; called by muse, mutect2, varscan2
- CENPH | c.180G>A p.M60I | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV51584175; called by muse, mutect2
- CEP170B | c.3022T>C p.S1008P (on ENST00000453495; = p.S937P on NM_015005.3) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV69023206; called by muse, mutect2, varscan2
- CHRD | c.2200C>T p.R734* | Nonsense Mutation (SNP) | VAF 9/68 reads (13%) | catalogued as rs1177348589, COSV52605456; called by muse, mutect2, varscan2
- CHRM3 | c.523A>G p.T175A | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55080244; called by muse, mutect2, varscan2
- CHRM3 | c.1700del p.K567Rfs*31 | Frame Shift Del (DEL) | VAF 12/68 reads (18%) | catalogued as rs751548647; called by mutect2, varscan2
- CHRNA4 | c.1616C>T p.S539L | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs375524982, CM1212665, COSV64719127; called by muse, mutect2, varscan2
- CHRND | c.517A>G p.K173E | Missense Mutation (SNP) | VAF 13/155 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as COSV51317367; called by muse, mutect2
- CHST8 | c.1142C>T p.A381V | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.773); catalogued as COSV52856269, COSV99381656; called by muse, mutect2, varscan2
- CIC | c.1930G>T p.G644* | Nonsense Mutation (SNP) | VAF 16/80 reads (20%) | catalogued as COSV50547333; called by muse, mutect2, varscan2
- CIC | c.2302C>A p.P768T | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.992); catalogued as COSV50547358, COSV50638716; called by muse, mutect2
- CKAP2 | c.1817del p.K606Rfs*14 (on ENST00000378037 / NM_001098525.2; = p.K605Rfs*14 on NM_018204.5) | Frame Shift Del (DEL) | VAF 9/41 reads (22%) | catalogued as rs752250702; called by mutect2, varscan2
- CLASP2 | c.2896del p.M966Wfs*33 (on ENST00000359576; = p.M965Wfs*33 on NM_015097.3 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 27/177 reads (15%) | catalogued as rs761731080; called by mutect2, varscan2
- CLDN1 | c.314T>C p.M105T | Missense Mutation (SNP) | VAF 40/302 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV55043467; called by muse, varscan2
- CLDN9 | c.537del p.L180Sfs*196 | Frame Shift Del (DEL) | VAF 5/42 reads (12%) | catalogued as rs763852712; called by mutect2, varscan2
- CLGN | c.656del p.K219Sfs*14 | Frame Shift Del (DEL) | VAF 21/115 reads (18%) | catalogued as COSV57773501; called by mutect2, pindel, varscan2
- CNGB1 | c.3737G>T p.R1246M | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV51897661; called by muse, mutect2
- CNTRL | c.2512A>G p.K838E | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV53043177; called by muse, mutect2, varscan2
- COL20A1 | c.2683del p.L895Yfs*27 | Frame Shift Del (DEL) | VAF 15/80 reads (19%) | catalogued as rs1339972284; called by mutect2, pindel, varscan2
- COL2A1 | c.310-1G>T p.X104_splice | Splice Site (SNP) | VAF 15/105 reads (14%) | catalogued as COSV61527832, COSV61532029; called by muse, mutect2, varscan2
- COL6A1 | c.76C>A p.P26T | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.013); catalogued as COSV62611517; called by muse, mutect2
- COL6A2 | c.169G>A p.V57I | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated (0.97); PolyPhen benign (0.1); catalogued as rs768434256, COSV55998741, COSV56014057; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL7A1 | c.188G>T p.G63V | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52550879, COSV99178951; called by muse, mutect2
- COMT | c.752G>T p.R251M | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV52889080; called by muse, mutect2, varscan2
- CORO2A | c.544G>A p.V182M | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.491); catalogued as rs1489748093, COSV59661956; called by muse, mutect2, varscan2
- CPSF2 | c.463A>G p.I155V | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.401); catalogued as COSV54097006; called by muse, mutect2, varscan2
- CRIPT | c.132del p.A45Qfs*86 | Frame Shift Del (DEL) | VAF 7/57 reads (12%) | catalogued as rs771238795; called by mutect2, pindel, varscan2
- CRYGA | c.476del p.G159Vfs*9 | Frame Shift Del (DEL) | VAF 22/191 reads (12%) | catalogued as rs762650691; called by mutect2, pindel, varscan2
- CSF1 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 30/287 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60031920; called by muse, mutect2, varscan2
- CSF2RA | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 37/298 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs761247845, COSV62623495; called by muse, mutect2, varscan2
- CSGALNACT2 | c.1238C>A p.P413H | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV65675034; called by muse, mutect2, varscan2
- CTCFL | c.135T>G p.S45R | Missense Mutation (SNP) | VAF 88/368 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV54770728; called by muse, mutect2, varscan2
- CTSC | c.479A>G p.Q160R | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV57056077; called by muse, mutect2, varscan2
- CTSW | c.586G>A p.V196I | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as rs150421438; called by muse, mutect2, varscan2
- CUL7 | c.1151G>A p.R384Q | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754112592, COSV54813079; called by muse, mutect2, varscan2
- CUL9 | c.2296C>T p.P766S | Missense Mutation (SNP) | VAF 44/393 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.444); catalogued as rs779551048; called by muse, mutect2, varscan2
- CWC27 | c.1076A>G p.E359G | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV66883990; called by muse, mutect2
- CXCL17 | c.80-1G>T p.X27_splice | Splice Site (SNP) | VAF 15/117 reads (13%) | catalogued as COSV59408496; called by muse, mutect2, varscan2
- DCD | c.214G>A p.G72R | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.98); catalogued as rs374154248; called by muse, mutect2, varscan2
- DCST2 | c.524A>G p.D175G | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); catalogued as rs376003986; called by muse, mutect2, varscan2
- DDX10 | c.1972G>T p.E658* | Nonsense Mutation (SNP) | VAF 8/71 reads (11%) | catalogued as COSV59431467; called by muse, mutect2, varscan2
- DDX23 | c.1286G>A p.R429H | Missense Mutation (SNP) | VAF 25/186 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.284); catalogued as rs761752687, COSV57282009; called by muse, mutect2, varscan2
- DDX27 | c.1280G>A p.S427N | Missense Mutation (SNP) | VAF 23/235 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.17); catalogued as COSV65605122; called by muse, mutect2
- DENND2B | c.2195T>C p.M732T | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as rs761628009, COSV58201159; called by muse, mutect2, varscan2
- DENND6B | c.403T>C p.Y135H | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.982); catalogued as COSV69806590; called by muse, mutect2
- DGKZ | c.3049C>T p.H1017Y (on ENST00000454345 / NM_001105540.2; = p.H829Y on NM_003646.4) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs964305814, COSV58984347; called by muse, mutect2, varscan2
- DHX58 | c.1631G>T p.R544L | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.282); catalogued as COSV52424573; called by muse, mutect2
- DHX8 | c.1636A>G p.N546D | Missense Mutation (SNP) | VAF 19/185 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.057); catalogued as COSV52250948; called by muse, mutect2
- DICER1 | c.4792G>A p.D1598N | Missense Mutation (SNP) | VAF 48/409 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs757177980, COSV58615716; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DIP2A | c.4522C>T p.Q1508* | Nonsense Mutation (SNP) | VAF 12/78 reads (15%) | catalogued as COSV59471935; called by muse, mutect2, varscan2
- DISP1 | c.3103A>G p.N1035D | Missense Mutation (SNP) | VAF 36/254 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs757026962, COSV52654589; called by muse, varscan2
- DLGAP2 | c.946A>G p.N316D | Missense Mutation (SNP) | VAF 19/168 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.075); catalogued as COSV101421443; called by muse, mutect2, varscan2
- DLGAP4 | c.1061C>T p.A354V | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV59414453; called by muse, mutect2
- DLL4 | c.1580T>C p.F527S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.69); catalogued as COSV51060944; called by muse, mutect2
- DMKN | c.1364del p.G455Efs*19 | Frame Shift Del (DEL) | VAF 11/93 reads (12%) | catalogued as rs758253239; called by mutect2, pindel, varscan2
- DMWD | c.1078G>A p.V360M | Missense Mutation (SNP) | VAF 15/154 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752095405, COSV52175525; called by muse, mutect2, varscan2
- DMXL2 | c.1873G>A p.A625T | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.993); catalogued as COSV51840815; called by muse, mutect2, varscan2
- DNAH10 | c.6544G>A p.V2182I (on ENST00000409039; = p.V2121I on NM_207437.3) | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs771895256, COSV68987865; called by muse, mutect2
- DNAH7 | c.3770del p.N1257Ifs*11 | Frame Shift Del (DEL) | VAF 10/76 reads (13%) | catalogued as rs34468832; called by mutect2, varscan2
- DNAJB7 | c.884del p.K295Rfs*25 | Frame Shift Del (DEL) | VAF 10/74 reads (14%) | catalogued as rs768619916; called by mutect2, varscan2
- DNAJC15 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.913); catalogued as rs1349719274, COSV64871767; called by muse, mutect2, varscan2
- DNAJC27 | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as rs746614892, COSV53094248; called by muse, mutect2, varscan2
- DNM2 | c.359T>C p.I120T | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58957154; called by muse, mutect2, varscan2
- DNMBP | c.400C>A p.H134N | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV60620380; called by muse, mutect2, varscan2
- DOCK3 | c.4847T>C p.I1616T | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.489); catalogued as rs752490310, COSV56502969; called by muse, mutect2, varscan2
- DPYD | c.2121del p.F707Lfs*4 | Frame Shift Del (DEL) | VAF 32/221 reads (14%) | catalogued as rs1475611014; called by mutect2, varscan2
- DRD3 | c.474G>A p.W158* | Nonsense Mutation (SNP) | VAF 15/115 reads (13%) | catalogued as COSV55678630; called by muse, mutect2, varscan2
- DSCAM | c.5564C>T p.T1855M | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs200410460; called by muse, mutect2, varscan2
- DSG3 | c.715G>T p.G239C | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57124199, COSV57129631; called by muse, varscan2
- DSP | c.6223C>T p.R2075W | Missense Mutation (SNP) | VAF 24/202 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as rs751050235, COSV65791139; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DSP | c.7649G>T p.G2550V | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65791144, COSV65796684; called by muse, mutect2, varscan2
- DSTYK | c.2185G>A p.A729T | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV65685309, COSV65686775; called by muse, mutect2, varscan2
- DTX4 | c.1527del p.G510Afs*35 | Frame Shift Del (DEL) | VAF 7/50 reads (14%) | catalogued as rs762133243; called by mutect2, pindel, varscan2
- DUSP18 | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.604); catalogued as rs202138261; called by muse, mutect2, varscan2
- DUSP26 | c.226A>G p.M76V | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs769544629; called by muse, mutect2
- DYNC1I2 | c.169del p.R57Gfs*13 | Frame Shift Del (DEL) | VAF 6/12 reads (50%) | catalogued as rs772082432; called by mutect2, varscan2
- ECM1 | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 41/317 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150625690; called by muse, mutect2, varscan2
- EFNA4 | c.535dup p.D179Gfs*65 | Frame Shift Ins (INS) | VAF 11/69 reads (16%) | catalogued as rs754580525; called by mutect2, varscan2
- EGFR | c.1051A>G p.I351V | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767790289, COSV51771322; called by muse, mutect2, varscan2
- EHD2 | c.968G>T p.G323V | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV54406749; called by muse, mutect2, varscan2
- EHF | c.342C>T p.N114= | Splice Region (SNP) | VAF 23/226 reads (10%) | catalogued as rs907609906, COSV57668234, COSV57669410; called by muse, mutect2, varscan2
- EHF | c.833G>A p.R278H | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs775169543, COSV57667511; called by muse, mutect2, varscan2
- EIF5 | c.1232T>C p.V411A | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (0.76); PolyPhen benign (0.007); catalogued as COSV53684713; called by muse, mutect2, varscan2
- ELL2 | c.937G>A p.A313T | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs150945042; called by mutect2, varscan2
- EMID1 | c.385C>T p.R129W | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs202116371, COSV61828467; called by muse, mutect2, varscan2
- EMILIN3 | c.1380del p.W461Gfs*21 | Frame Shift Del (DEL) | VAF 22/176 reads (13%) | catalogued as rs759858342; called by mutect2, pindel
- EML4 | c.574C>T p.R192C | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.614); catalogued as rs376838322; called by muse, mutect2, varscan2
- EPB41L1 | c.1586A>T p.D529V | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV52433624; called by muse, mutect2, varscan2
- EPB41L3 | c.640G>A p.V214M | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs775170222, COSV59444488; called by muse, mutect2
- EPDR1 | c.442G>A p.V148I | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.357); catalogued as rs369217258; called by muse, mutect2
- EPG5 | c.5143A>G p.K1715E | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.036); catalogued as COSV56344590; called by muse, mutect2
- EPYC | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as rs745867926, COSV53798426, COSV53800078; called by muse, mutect2, varscan2
- ERAP1 | c.1366G>A p.A456T | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs150674566; called by muse, mutect2, varscan2
- ERICH3 | c.2090A>C p.K697T | Missense Mutation (SNP) | VAF 29/220 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV58599194; called by muse, mutect2, varscan2
- ERN2 | c.2108C>T p.A703V | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55620606; called by muse, mutect2
- ERVFRD-1 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 47/366 reads (13%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs140934168; called by muse, mutect2, varscan2
- EVC2 | c.878C>A p.P293Q | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as COSV60387853; called by mutect2, varscan2
- EVX2 | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.196); catalogued as COSV57962462; called by muse, mutect2, varscan2
- FAM217A | c.989T>C p.V330A | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV51158892; called by muse, mutect2, varscan2
- FAM53C | c.461del p.G154Vfs*152 | Frame Shift Del (DEL) | VAF 15/156 reads (10%) | catalogued as COSV53513030; called by mutect2, pindel
- FAT1 | c.10162G>A p.V3388I | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as rs753202486, COSV101498964, COSV71671938; called by muse, mutect2, varscan2
- FAT4 | c.4358G>A p.G1453D | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1471062955, COSV67881330; called by muse, mutect2
- FBN1 | c.6242A>G p.Q2081R | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); catalogued as COSV57309345; called by muse, mutect2, varscan2
- FCRL5 | c.2476G>A p.G826R | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as COSV62511447; called by muse, mutect2, varscan2
- FCRLA | c.476C>A p.A159E (on ENST00000367959; = p.A136E on NM_032738.4) | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.757); catalogued as COSV52684282; called by muse, mutect2, varscan2
- FETUB | c.437del p.K146Rfs*4 | Frame Shift Del (DEL) | VAF 20/97 reads (21%) | catalogued as rs748969702; called by mutect2, varscan2
- FEZF2 | c.946C>A p.Q316K | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.973); catalogued as COSV51861903; called by muse, mutect2, varscan2
- FGA | c.2560A>G p.R854G | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.828); catalogued as rs747707945, COSV57393132; called by muse, mutect2
- FGFR2 | c.269A>C p.E90A | Missense Mutation (SNP) | VAF 17/167 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV60639932; called by muse, mutect2, varscan2
- FIZ1 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as rs1231363407, COSV55607080; called by muse, mutect2, varscan2
- FLNB | c.3101C>A p.A1034D | Missense Mutation (SNP) | VAF 23/218 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55870259; called by muse, mutect2, varscan2
- FLT1 | c.2401C>A p.P801T | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.138); catalogued as rs1304736848, COSV56717806; called by muse, mutect2
- FLT4 | c.3179G>A p.R1060Q | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757396801, COSV56098351, COSV56126835; called by muse, mutect2, varscan2
- FOSL2 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs375020008, COSV99268383; called by muse, mutect2, varscan2
- FOXD4 | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 56/976 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58698344, COSV58703688; called by muse, mutect2
- FOXN2 | c.780G>T p.K260N | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as COSV61317014; called by muse, mutect2, varscan2
- FPR3 | c.887G>A p.C296Y | Missense Mutation (SNP) | VAF 25/236 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV59328238; called by muse, mutect2, varscan2
- FRMD4A | c.3014del p.P1005Qfs*8 | Frame Shift Del (DEL) | VAF 12/118 reads (10%) | catalogued as rs752538869; called by mutect2, varscan2
- FRMPD2 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as rs1482187278, COSV59715224; called by muse, mutect2, varscan2
- FRMPD3 | c.1625G>A p.S542N | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.244); catalogued as COSV99345933; called by muse, mutect2, varscan2
- FRY | c.2281G>A p.V761I | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs758925707, COSV66565160; called by muse, mutect2, varscan2
- FSCN3 | c.756G>T p.R252S | Missense Mutation (SNP) | VAF 13/137 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as rs1193316872, COSV50000216; called by muse, mutect2, varscan2
- FSTL4 | c.2369del p.G790Vfs*6 | Frame Shift Del (DEL) | VAF 8/44 reads (18%) | catalogued as rs765771244; called by mutect2, pindel, varscan2
- FTSJ3 | c.2072G>A p.R691Q | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs1324648548, COSV63789308; called by muse, mutect2, varscan2
- FYN | c.1394T>C p.V465A | Missense Mutation (SNP) | VAF 28/267 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as COSV57609821; called by muse, mutect2, varscan2
- G6PC3 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 34/264 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs778919305, COSV52241952; called by muse, mutect2, varscan2
- GAB4 | c.153del p.E52Rfs*4 | Frame Shift Del (DEL) | VAF 6/35 reads (17%) | catalogued as rs764879401, COSV68754102; called by mutect2, pindel, varscan2
- GABRP | c.14T>A p.L5H | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.21); catalogued as COSV54661333; called by muse, mutect2
- GAS2L1 | c.844C>T p.R282C | Missense Mutation (SNP) | VAF 27/249 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.394); catalogued as rs779636685, COSV53329906; called by muse, mutect2, varscan2
- GATAD2A | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1008975400, COSV53066398; called by muse, mutect2, varscan2
- GBA | c.514T>C p.Y172H | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59168960; called by muse, mutect2, varscan2
- GBP7 | c.1293dup p.H432Afs*12 | Frame Shift Ins (INS) | VAF 30/144 reads (21%) | catalogued as rs754177800; called by mutect2, varscan2
- GBX1 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs778239687, COSV52546614; called by muse, mutect2
- GCC1 | c.1706G>A p.R569Q | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as rs777111161, COSV58461754; called by muse, mutect2, varscan2
- GCFC2 | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV58079561; called by muse, mutect2, varscan2
- GDF5 | c.67T>C p.C23R | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.015); catalogued as COSV65499371; called by muse, mutect2, varscan2
- GDF9 | c.457T>G p.L153V | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs1247729056, COSV51525777; called by muse, mutect2, varscan2
- GFM2 | c.703G>A p.V235M | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.423); catalogued as rs146259893; called by muse, mutect2, varscan2
- GGH | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as rs528348849, COSV52649196; called by muse, mutect2, varscan2
- GGT7 | c.555C>T p.G185= | Splice Region (SNP) | VAF 20/111 reads (18%) | catalogued as COSV60539636; called by muse, mutect2, varscan2
- GIMAP8 | c.452dup p.N151Kfs*12 | Frame Shift Ins (INS) | VAF 12/95 reads (13%) | catalogued as rs746795576; called by mutect2, varscan2
- GIPC3 | c.380C>T p.T127M | Missense Mutation (SNP) | VAF 20/185 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1017753310, COSV59258261; called by muse, mutect2, varscan2
- GLB1L3 | c.613A>G p.I205V | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as COSV66280494; called by muse, mutect2
- GMIP | c.1309T>G p.S437A | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV52554195; called by muse, mutect2
- GMPPB | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.099); catalogued as rs755165049, COSV57537510; ClinVar: uncertain significance; called by mutect2, varscan2
- GNB1L | c.227C>T p.T76M | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as rs765685532, COSV61547693; called by muse, mutect2, varscan2
- GNE | c.470T>C p.M157T (on ENST00000396594 / NM_001128227.3; = p.M126T on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV64951250; called by muse, mutect2, varscan2
- GOLPH3 | c.878T>C p.V293A | Missense Mutation (SNP) | VAF 23/181 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.034); catalogued as rs760560885, COSV54059724; called by muse, mutect2, varscan2
- GON4L | c.3070C>T p.R1024* | Nonsense Mutation (SNP) | VAF 15/151 reads (10%) | catalogued as COSV55186669; called by muse, mutect2, varscan2
- GP9 | c.96G>T p.M32I | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.339); catalogued as COSV56623770; called by muse, mutect2, varscan2
- GREB1 | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1297512255, COSV52180598; called by muse, mutect2, varscan2
- GRIA2 | c.2218G>A p.D740N | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs1276241823, COSV52382522; called by muse, mutect2, varscan2
- GRID1 | c.1082G>A p.G361D | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60014184; called by muse, mutect2, varscan2
- GRIN2B | c.3316G>A p.E1106K | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs199799650, COSV74204786, COSV74206480; called by muse, mutect2, varscan2
- GRM1 | c.3078G>T p.Q1026H | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.271); catalogued as COSV51109063; called by muse, varscan2
- GRM5 | c.2024G>T p.G675V | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59590792, COSV59634994; called by muse, mutect2, varscan2
- GRM5 | c.649G>A p.V217M | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV59590806; called by muse, mutect2, varscan2
- GUCY2C | c.2039_2041del p.F680del | In Frame Del (DEL) | VAF 7/50 reads (14%) | catalogued as rs748750136; called by mutect2, pindel, varscan2
- GUSB | c.1646T>C p.F549S | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); catalogued as COSV59220893; called by muse, mutect2, varscan2
- GXYLT1 | c.977T>C p.F326S | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1268145319, COSV55132495; called by mutect2, varscan2
- HAPLN2 | c.35G>A p.R12H | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs766935922, COSV54815244; called by muse, mutect2, varscan2
- HCAR2 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs200534953; called by muse, mutect2, varscan2
- HDAC7 | c.674C>T p.S225L (on ENST00000427332; = p.S264L on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as rs771710279, COSV50319242; called by muse, mutect2, varscan2
- HECTD4 | c.1547T>C p.L516P | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764673654, COSV66386715; called by muse, mutect2, varscan2
- HECW1 | c.937G>A p.A313T | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as rs1562974259, COSV67821840; called by muse, mutect2, varscan2
- HELLS | c.1840del p.R614Efs*11 | Frame Shift Del (DEL) | VAF 13/55 reads (24%) | catalogued as rs745837238; called by mutect2, varscan2
- HEMGN | c.389A>G p.E130G | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.422); catalogued as COSV52325149, COSV99412523; called by muse, mutect2, varscan2
- HERPUD2 | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); catalogued as COSV60943858; called by muse, mutect2, varscan2
- HES3 | c.14G>A p.R5H | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs781716588, COSV64938150; called by muse, mutect2, varscan2
- HEXD | c.1196G>A p.R399H (on ENST00000327949 / NM_001369487.1; = p.A429T on NM_173620.3) | Missense Mutation (SNP) | VAF 32/254 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs760603638, COSV60062772; called by muse, mutect2, varscan2
- HGH1 | c.986C>T p.T329M | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs1050991819; called by muse, mutect2
- HIC2 | c.32G>A p.C11Y | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs771349850, COSV68041742; called by muse, mutect2, varscan2
- HIRA | c.2807G>A p.R936H | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.027); catalogued as rs782037801, COSV54272101; called by muse, mutect2, varscan2
- HNRNPD | c.773T>C p.M258T | Missense Mutation (SNP) | VAF 35/318 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV100002804; called by muse, mutect2, varscan2
- HNRNPUL2 | c.856G>A p.G286R | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53665099; called by muse, mutect2
- HOGA1 | c.122del p.P41Lfs*2 | Frame Shift Del (DEL) | VAF 17/133 reads (13%) | catalogued as CM122019; called by mutect2, pindel, varscan2
- HOXA4 | c.112G>A p.G38R | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.67); catalogued as rs746129531, COSV57825070; called by muse, mutect2
- HOXA9 | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.014); catalogued as COSV58655799; called by muse, mutect2
- HPX | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764988248, COSV56418537; called by muse, mutect2, varscan2
- HSD17B2 | c.638G>T p.R213M | Missense Mutation (SNP) | VAF 21/165 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52274320; called by muse, mutect2, varscan2
- HSPA1L | c.123del p.S42Afs*20 | Frame Shift Del (DEL) | VAF 19/169 reads (11%) | catalogued as rs1562343047; called by mutect2, pindel, varscan2
- HSPA6 | c.1009G>A p.V337I | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as rs1157013376, COSV59059948; called by muse, mutect2
- HTR7 | c.1421del p.K474Rfs*3 (on ENST00000336152 / NM_019859.4; = p.G442Vfs*6 on NM_000872.5) | Frame Shift Del (DEL) | VAF 9/79 reads (11%) | catalogued as COSV53287248; called by mutect2, pindel, varscan2
- HUNK | c.947C>T p.A316V | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as rs755514543, COSV54224504; called by muse, mutect2, varscan2
- HUS1B | c.481C>T p.R161C | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.531); catalogued as rs201176240, COSV57861162; called by muse, mutect2
- HYAL1 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 28/186 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.012); catalogued as COSV56496746; called by muse, mutect2, varscan2
- HYAL3 | c.1211C>T p.P404L | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.065); catalogued as COSV60186358; called by muse, mutect2, varscan2
- IBTK | c.2752G>A p.G918S | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.05); catalogued as rs777051108, COSV60390883; called by muse, mutect2, varscan2
- ICA1 | c.611del p.N204Tfs*5 | Frame Shift Del (DEL) | VAF 10/70 reads (14%) | catalogued as rs747841314; called by mutect2, varscan2
- IFIT1 | c.1007del p.K336Sfs*9 | Frame Shift Del (DEL) | VAF 10/78 reads (13%) | catalogued as rs1202143274; called by mutect2, pindel, varscan2
- IFITM1 | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as COSV100068203; called by muse, mutect2
- IFNGR1 | c.165G>T p.Q55H | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.07); catalogued as COSV62989404, COSV62989595; called by muse, mutect2, varscan2
- IGF2BP2 | c.1471C>T p.R491W | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.204); catalogued as rs1160344547, COSV60482966; called by muse, mutect2, varscan2
- IGF2R | c.3949del p.D1317Tfs*27 | Frame Shift Del (DEL) | VAF 54/196 reads (28%) | catalogued as rs760021495; called by mutect2, varscan2
- IGFBP5 | c.605A>C p.E202A | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.424); catalogued as COSV52082015; called by muse, mutect2, varscan2
- IGHV3-15 | c.105del p.S36Pfs*18 | Frame Shift Del (DEL) | VAF 15/155 reads (10%) | catalogued as rs781984574; called by mutect2, pindel, varscan2
- IGLV3-16 | c.147del p.K49Nfs*17 | Frame Shift Del (DEL) | VAF 15/119 reads (13%) | catalogued as rs746629447; called by mutect2, pindel, varscan2
- IGSF3 | c.1556C>T p.A519V (on ENST00000369486 / NM_001007237.3; = p.A539V on NM_001542.4) | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.057); catalogued as COSV100604352; called by muse, mutect2
- IGSF9 | c.1789G>A p.E597K (on ENST00000368094 / NM_001135050.2; = p.E581K on NM_020789.4) | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV63638758; called by muse, mutect2, varscan2
- IKZF3 | c.1357C>T p.R453W | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs1434210451, COSV53099584; called by muse, mutect2, varscan2
- IL5RA | c.665C>A p.S222Y | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as rs1425823311, COSV56520707, COSV56521023, COSV99843229; called by muse, mutect2, varscan2
- ILF3 | c.488C>A p.P163H | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51554181; called by muse, mutect2, varscan2
- INCENP | c.875C>T p.T292M | Missense Mutation (SNP) | VAF 24/191 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs751814772, COSV53913170; called by muse, mutect2, varscan2
- INSIG2 | c.187A>T p.I63F | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as COSV55521841; called by muse, mutect2
- INTS11 | c.1012C>T p.R338W | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs749306909, COSV60087454; called by muse, mutect2, varscan2
- IPO7 | c.947A>G p.Y316C | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65684209; called by muse, mutect2
- IPPK | c.488T>C p.M163T | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55332464; called by muse, mutect2
- IQCA1 | c.2020C>T p.R674W | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772085966, COSV54495832; called by muse, mutect2, varscan2
- IQCN | c.3531G>A p.W1177* | Nonsense Mutation (SNP) | VAF 16/92 reads (17%) | catalogued as COSV62746952; called by muse, mutect2, varscan2
- IRS1 | c.1791del p.H598Tfs*38 | Frame Shift Del (DEL) | VAF 8/56 reads (14%) | catalogued as rs761880048; called by mutect2, varscan2
- IRX2 | c.353G>C p.R118P | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs1410586686, COSV57409668; called by muse, mutect2
- ITGAX | c.1549C>T p.P517S | Missense Mutation (SNP) | VAF 19/184 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV51641530; called by muse, mutect2, varscan2
- ITPR2 | c.7250del p.L2417* | Frame Shift Del (DEL) | VAF 13/101 reads (13%) | catalogued as rs1288961144; called by mutect2, varscan2
- KAT2A | c.967C>T p.R323W | Missense Mutation (SNP) | VAF 21/224 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1555666795, COSV56789274; called by muse, mutect2
- KAT6A | c.932G>A p.R311Q | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.442); catalogued as rs1291997106, COSV55902648; called by muse, mutect2, varscan2
- KCNA10 | c.589G>T p.D197Y | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as rs867498115, COSV63904190, COSV63904851; called by muse, mutect2, varscan2
- KCND3 | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1444134502, COSV56175044; called by muse, mutect2, varscan2
- KCNJ12 | c.553G>A p.A185T | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.919); catalogued as rs782390309, COSV59163347; called by muse, mutect2
- KCNK13 | c.55C>T p.R19C | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56410613, COSV99965541; called by muse, mutect2, varscan2
- KCNK15 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV65719109; called by muse, mutect2
- KCNN2 | c.1369C>T p.Q457* (on ENST00000264773; = p.Q669* on NM_021614.4) | Nonsense Mutation (SNP) | VAF 8/58 reads (14%) | catalogued as COSV53283159; called by muse, mutect2, varscan2
- KCNT2 | c.1500dup p.A501Cfs*2 | Frame Shift Ins (INS) | VAF 10/84 reads (12%) | catalogued as rs1249079077; called by mutect2, pindel, varscan2
- KCTD10 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV57325812; called by muse, mutect2, varscan2
- KDM2A | c.3293A>G p.E1098G | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as COSV58188566; called by muse, mutect2, varscan2
- KDM4A | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64958809; called by muse, mutect2, varscan2
- KDM5C | c.3120+2T>C p.X1040_splice | Splice Site (SNP) | VAF 5/12 reads (42%) | catalogued as COSV64762745; called by muse, mutect2, varscan2
- KDM5D | c.3861T>A p.D1287E | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58736027; called by muse, mutect2, varscan2
- KHK | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.635); catalogued as rs777377724, COSV53148305; called by muse, mutect2
- KIAA1217 | c.4715del p.K1572Sfs*32 | Frame Shift Del (DEL) | VAF 18/176 reads (10%) | catalogued as rs1352713861; called by mutect2, pindel, varscan2
- KIF2A | c.1669C>A p.P557T | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1233263818, COSV66944530; called by muse, mutect2, varscan2
- KIF6 | c.148A>G p.N50D | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV54667157; called by muse, mutect2, varscan2
- KLHL32 | c.1272C>A p.N424K | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65110469; called by muse, mutect2, varscan2
- KLKB1 | c.257C>T p.T86I | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV52993927; called by muse, mutect2
- KMT2A | c.1259G>A p.R420Q | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.992); catalogued as rs1555035885, COSV63282010; called by muse, mutect2, varscan2
- KMT2C | c.11787A>C p.K3929N | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV51290982; called by muse, mutect2, varscan2
- KMT2D | c.4251G>A p.M1417I | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.626); catalogued as rs200353763, COSV99979068, COSV99985593; called by mutect2, varscan2
- KPRP | c.1718A>G p.E573G | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV64220965; called by muse, mutect2
- KRTAP10-9 | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 27/253 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV59951852; called by muse, mutect2, varscan2
- KRTAP4-5 | c.287G>A p.C96Y | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.282); catalogued as COSV100576842, COSV58351676; called by muse, mutect2, varscan2
- KTI12 | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT tolerated (0.66); PolyPhen benign (0.005); catalogued as rs781735198, COSV65405585; called by muse, mutect2, varscan2
- L3MBTL1 | c.1336C>T p.R446C (on ENST00000418998 / NM_001377303.1; = p.R356C on NM_015478.7) | Missense Mutation (SNP) | VAF 55/297 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748183406, COSV64227900; called by muse, mutect2, varscan2
- L3MBTL2 | c.1915C>T p.R639* | Nonsense Mutation (SNP) | VAF 8/61 reads (13%) | catalogued as rs151099443; called by muse, mutect2, varscan2
- LAMA1 | c.9215G>A p.G3072E | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs747602128, COSV67532138; called by muse, mutect2
- LAMA3 | c.8003G>C p.R2668T (on ENST00000313654 / NM_198129.4; = p.R1059T on NM_000227.6) | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV52529655; called by muse, mutect2
- LAMA5 | c.10111C>A p.L3371I | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.227); catalogued as COSV53352991, COSV53360378; called by muse, mutect2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 15/116 reads (13%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LATS1 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.388); catalogued as COSV53586233; called by muse, mutect2, varscan2
- LGI2 | c.485+1G>A p.X162_splice | Splice Site (SNP) | VAF 13/99 reads (13%) | catalogued as COSV66122321; called by muse, mutect2, varscan2
- LGR5 | c.2486A>G p.E829G | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as COSV57002272; called by muse, mutect2, varscan2
- LHX5 | c.542G>T p.R181L | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55661943; called by muse, mutect2, varscan2
- LIFR | c.1431A>C p.Q477H | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV54684567; called by muse, mutect2
- LIMCH1 | c.805T>C p.Y269H | Missense Mutation (SNP) | VAF 23/198 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV58273340; called by muse, mutect2, varscan2
- LMAN1L | c.61C>A p.H21N | Missense Mutation (SNP) | VAF 20/195 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.079); catalogued as COSV59000620; called by muse, mutect2, varscan2
- LOXL3 | c.824del p.G275Afs*5 | Frame Shift Del (DEL) | VAF 16/120 reads (13%) | catalogued as rs746133895; called by mutect2, varscan2
- LRFN3 | c.551C>T p.T184M | Missense Mutation (SNP) | VAF 20/221 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1455350413, COSV55816914; called by muse, mutect2
- LRFN4 | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.682); catalogued as rs1047561616, COSV58920664; called by muse, mutect2, varscan2
- LRIT1 | c.58C>T p.R20W | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as rs149315483, COSV63893366; called by muse, mutect2, varscan2
- LRP10 | c.184C>A p.L62M | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.191); catalogued as COSV62077669; called by muse, mutect2, varscan2
- LRRC8A | c.1697G>A p.G566D | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV52184076; called by mutect2, varscan2
- LTBP3 | c.1312G>A p.A438T | Missense Mutation (SNP) | VAF 16/169 reads (9%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.503); catalogued as rs368676768; called by muse, mutect2
- LTN1 | c.1239del p.F413Lfs*7 | Frame Shift Del (DEL) | VAF 14/131 reads (11%) | catalogued as rs1568851261; called by mutect2, pindel, varscan2
- LYST | c.10253C>T p.A3418V | Missense Mutation (SNP) | VAF 49/305 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV67703305; called by muse, mutect2, varscan2
- MACF1 | c.1760G>A p.R587Q | Missense Mutation (SNP) | VAF 35/239 reads (15%) | catalogued as rs750364998, COSV58359492; called by muse, mutect2, varscan2
- MADD | c.2563C>T p.R855W | Missense Mutation (SNP) | VAF 26/225 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.884); catalogued as rs144471266; called by muse, mutect2, varscan2
- MAGEC1 | c.1046C>T p.T349I | Missense Mutation (SNP) | VAF 44/177 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.077); catalogued as COSV53567974; called by muse, mutect2, varscan2
- MAGEE2 | c.133del p.Q45Sfs*27 | Frame Shift Del (DEL) | VAF 13/41 reads (32%) | catalogued as rs1159257962; called by mutect2, pindel, varscan2
- MAK | c.1805G>A p.R602H | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs777002916, COSV57564075; called by muse, mutect2, varscan2
- MALT1 | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs763701192, COSV61934050; called by muse, mutect2, varscan2
- MAN1B1 | c.458C>T p.S153L | Missense Mutation (SNP) | VAF 34/205 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs754933555, COSV64306148; called by muse, mutect2, varscan2
- MANEA | c.169A>G p.K57E | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.055); catalogued as COSV62589246; called by muse, mutect2, varscan2
- MAP2K7 | c.463G>A p.G155R | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.972); catalogued as COSV67607605; called by muse, mutect2
- MAP3K4 | c.1288C>A p.P430T | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.309); catalogued as COSV62330150; called by muse, mutect2, varscan2
- MAP3K4 | c.3275C>T p.A1092V | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1180796133, COSV62330152; called by muse, mutect2, varscan2
- MAPK7 | c.548T>C p.L183P | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55189297; called by muse, mutect2
- MARK2 | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 26/200 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59280386; called by muse, mutect2, varscan2
- MATN4 | c.1223T>C p.F408S (on ENST00000372754; = p.F367S on NM_003833.4) | Missense Mutation (SNP) | VAF 29/117 reads (25%) | PolyPhen probably damaging (0.999); catalogued as COSV61350360; called by muse, mutect2, varscan2
- MBD2 | c.665_668del p.K222Rfs*17 | Frame Shift Del (DEL) | VAF 26/165 reads (16%) | catalogued as rs760961363; called by pindel, varscan2
- MBD5 | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs201699340, COSV68695760; called by muse, mutect2, varscan2
- MCM2 | c.1313T>A p.V438D | Missense Mutation (SNP) | VAF 30/192 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV54032022; called by muse, mutect2, varscan2
- MDN1 | c.15238T>G p.F5080V | Missense Mutation (SNP) | VAF 35/258 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV65517201; called by muse, mutect2, varscan2
- MECR | c.844A>G p.M282V | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV55284183; called by muse, mutect2, varscan2
- MED14 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs758523518, COSV61355863; called by muse, mutect2, varscan2
- MED15 | c.786G>T p.Q262H | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.776); catalogued as COSV53026783; called by muse, mutect2, varscan2
- MED26 | c.655G>T p.G219C | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.174); catalogued as COSV54658670; called by muse, mutect2, varscan2
- MEOX2 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.212); catalogued as rs759767365, COSV56287580; called by muse, varscan2
- MESD | c.632del p.K211Rfs*6 | Frame Shift Del (DEL) | VAF 14/72 reads (19%) | catalogued as rs745891632; called by mutect2, varscan2
- MEX3A | c.1526A>G p.H509R | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.966); catalogued as COSV68478954; called by muse, mutect2, varscan2
- MEX3B | c.1037del p.G346Efs*181 | Frame Shift Del (DEL) | VAF 15/130 reads (12%) | catalogued as rs1406688622; called by mutect2, pindel, varscan2
- MFSD14A | c.806del p.L269Yfs*6 | Frame Shift Del (DEL) | VAF 20/152 reads (13%) | catalogued as rs780635289; called by mutect2, varscan2
- MIDEAS | c.2076T>G p.H692Q | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.806); catalogued as COSV54092630; called by muse, mutect2, varscan2
- MIEF1 | c.1012C>T p.R338W | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.05); catalogued as COSV57477590; called by muse, mutect2, varscan2
- MIOS | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60766930; called by muse, mutect2, varscan2
- MIP | c.413C>T p.T138M | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs121917867, CM000754; called by muse, mutect2, varscan2
- MNX1 | c.1030A>G p.S344G | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV53317648; called by muse, mutect2, varscan2
- MORF4L1 | c.1045G>A p.D349N (on ENST00000331268 / NM_206839.2; = p.D310N on NM_006791.4) | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.245); catalogued as rs1290285565, COSV58703789; called by muse, mutect2, varscan2
- MPG | c.635G>A p.R212H | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as rs142373562; called by muse, mutect2, varscan2
- MROH2B | c.4420C>T p.R1474C | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.409); catalogued as rs866826423, COSV68180688, COSV68180988; called by muse, mutect2
- MRPL54 | c.144del p.G49Vfs*3 | Frame Shift Del (DEL) | VAF 9/51 reads (18%) | catalogued as rs1340751683; called by mutect2, pindel, varscan2
- MSL2 | c.1120G>A p.V374M | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.234); catalogued as rs761704166, COSV53859626; called by muse, mutect2, varscan2
- MTARC2 | c.878T>C p.L293P | Missense Mutation (SNP) | VAF 20/173 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63765005; called by muse, mutect2, varscan2
- MTF2 | c.652C>T p.Q218* | Nonsense Mutation (SNP) | VAF 8/72 reads (11%) | catalogued as COSV64769511; called by muse, mutect2
- MTFR1L | c.227A>G p.Y76C | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV65355434; called by muse, mutect2, varscan2
- MTHFD1L | c.2513C>A p.S838* | Nonsense Mutation (SNP) | VAF 16/111 reads (14%) | catalogued as COSV66223737; called by muse, mutect2, varscan2
- MTIF2 | c.1864C>A p.P622T | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV55050185; called by muse, mutect2, varscan2
- MTIF2 | c.1417G>A p.A473T | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV55050193; called by muse, mutect2, varscan2
- MTNR1A | c.457C>T p.L153F | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as COSV56154977; called by muse, mutect2, varscan2
- MUC16 | c.16228G>A p.A5410T | Missense Mutation (SNP) | VAF 68/595 reads (11%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.021); catalogued as COSV67444967; called by muse, mutect2, varscan2
- MUC6 | c.4232C>A p.T1411K | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.072); catalogued as rs368570174, COSV70133860; called by muse, varscan2
- MVK | c.305C>A p.A102D | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.048); catalogued as COSV57330844; called by muse, mutect2, varscan2
- MYBL2 | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.017); catalogued as rs775568667, COSV53827546; called by mutect2, varscan2
- MYCBP2 | c.8554G>T p.E2852* (on ENST00000357337; = p.E2890* on NM_015057.5) | Nonsense Mutation (SNP) | VAF 7/107 reads (7%) | catalogued as COSV62010305; called by muse, mutect2
- MYH6 | c.5528G>T p.R1843M | Missense Mutation (SNP) | VAF 40/317 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59304799, COSV59305582; called by muse, mutect2, varscan2
- MYH7 | c.3442G>A p.E1148K | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs786205355, COSV100805865, COSV100806516; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH9 | c.2333A>C p.K778T | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV53381978; called by muse, mutect2, varscan2
- MYL3 | c.217T>C p.Y73H | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.947); catalogued as COSV52767323; called by muse, mutect2, varscan2
- MYLK | c.4922C>T p.A1641V | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.92); catalogued as COSV60604795; called by muse, mutect2, varscan2
- MYO10 | c.3674del p.G1225Afs*22 | Frame Shift Del (DEL) | VAF 23/160 reads (14%) | catalogued as rs760302326; called by mutect2, varscan2
- MYO1F | c.1450C>T p.Q484* | Nonsense Mutation (SNP) | VAF 10/72 reads (14%) | catalogued as COSV57791865; called by muse, mutect2, varscan2
- MYO1F | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs201191520; called by muse, mutect2, varscan2
- MYO6 | c.1202G>A p.G401D | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs747375619, COSV64117271; called by muse, mutect2, varscan2
- MYO6 | c.3536G>A p.R1179H (on ENST00000369981; = p.R1169H on NM_004999.4) | Missense Mutation (SNP) | VAF 30/208 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763284731, COSV64117282; called by muse, mutect2, varscan2
- NAA25 | c.2183G>A p.R728H | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs116838734, COSV55701991; called by muse, mutect2, varscan2
- NAA25 | c.1932_1934del p.E644del | In Frame Del (DEL) | VAF 35/257 reads (14%) | catalogued as rs775859917; called by pindel, varscan2
- NAB1 | c.1381C>A p.L461I | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.038); catalogued as COSV61608140; called by muse, mutect2
- NAPEPLD | c.842del p.F281Sfs*14 | Frame Shift Del (DEL) | VAF 18/103 reads (17%) | catalogued as rs746683932, COSV100439928; called by mutect2, varscan2
- NAV1 | c.4399A>G p.K1467E | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); catalogued as COSV55214056; called by muse, mutect2
- NAV2 | c.1073G>A p.S358N (on ENST00000396087 / NM_001244963.2; = p.S335N on NM_145117.5) | Missense Mutation (SNP) | VAF 37/320 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.063); catalogued as COSV62315364; called by muse, mutect2, varscan2
- NBEA | c.1954T>C p.W652R | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59760330; called by muse, mutect2, varscan2
- NBEAL2 | c.1795C>T p.P599S | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52754178; called by muse, mutect2, varscan2
- NCAPG | c.1477G>A p.A493T | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52268604; called by muse, mutect2, varscan2
- NCKAP5 | c.3604A>G p.T1202A | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.055); catalogued as COSV58427343; called by muse, mutect2, varscan2
- NCLN | c.1095G>T p.E365D | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV55741846; called by muse, mutect2
- NFAT5 | c.99G>T p.K33N | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV63025142; called by muse, mutect2, varscan2
- NFAT5 | c.3902A>G p.Q1301R | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1406507070, COSV63025155; called by muse, mutect2, varscan2
- NFATC4 | c.2591G>A p.S864N | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.014); catalogued as COSV51596500; called by muse, mutect2, varscan2
- NHLRC1 | c.612del p.F204Lfs*28 | Frame Shift Del (DEL) | VAF 9/72 reads (13%) | catalogued as rs1171412241, CD054388; called by mutect2, pindel, varscan2
- NID2 | c.2389C>T p.R797W | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as rs758169329, COSV53493011; called by muse, mutect2
- NIPAL4 | c.887T>C p.I296T | Missense Mutation (SNP) | VAF 33/245 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as COSV57422971; called by muse, mutect2, varscan2
- NKTR | c.2297del p.N766Ifs*30 | Frame Shift Del (DEL) | VAF 15/95 reads (16%) | catalogued as rs767007251; called by mutect2, varscan2
- NMBR | c.344G>A p.G115D | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV57800412; called by muse, mutect2
- NOBOX | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.389); catalogued as rs777495779, COSV56192652; called by muse, mutect2, varscan2
- NOC3L | c.2337C>A p.Y779* | Nonsense Mutation (SNP) | VAF 6/46 reads (13%) | catalogued as rs984487255, COSV64929614; called by muse, mutect2, varscan2
- NOP2 | c.1460G>A p.C487Y (on ENST00000322166 / NM_001258308.2; = p.C483Y on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as COSV59109440; called by muse, mutect2
- NOTCH2 | c.5770G>T p.G1924C | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56681632; called by muse, mutect2, varscan2
- NOTCH3 | c.3314del p.G1105Afs*167 | Frame Shift Del (DEL) | VAF 9/52 reads (17%) | catalogued as COSV54635564; called by mutect2, pindel, varscan2
- NOTUM | c.1357C>T p.R453* | Nonsense Mutation (SNP) | VAF 10/81 reads (12%) | catalogued as rs746437719, COSV68825740; called by muse, mutect2, varscan2
- NR3C2 | c.514G>A p.V172M | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV60985368; called by muse, mutect2
- NRDC | c.3611C>T p.A1204V | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.059); catalogued as COSV61401608; called by muse, mutect2, varscan2
- NRXN3 | c.1855C>T p.R619C (on ENST00000335750 / NM_001330195.2; = p.R246C on NM_004796.6) | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs764624479, COSV59714381; called by muse, mutect2, varscan2
- NTN1 | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1331242639, COSV51478158; called by muse, mutect2, varscan2
- NTSR2 | c.799G>A p.V267I | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.071); catalogued as rs1461394810, COSV60990387; called by muse, mutect2, varscan2
- NUP188 | c.4060G>A p.A1354T | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV65360294; called by muse, mutect2
- NUP58 | c.1667G>T p.S556I | Missense Mutation (SNP) | VAF 29/230 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67750892; called by muse, mutect2, varscan2
- OBSCN | c.4372del p.A1458Pfs*16 | Frame Shift Del (DEL) | VAF 8/51 reads (16%) | catalogued as COSV52805133; called by mutect2, pindel, varscan2
- OBSCN | c.8564C>T p.T2855M | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.9); catalogued as rs764532787, COSV52740026; called by muse, mutect2, varscan2
- ODF3L1 | c.452T>C p.V151A | Missense Mutation (SNP) | VAF 35/294 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0.108); catalogued as rs755278278, COSV59819882; called by muse, mutect2, varscan2
- OPA3 | c.16T>G p.F6V | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54398055; called by muse, mutect2, varscan2
- OR10A5 | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.711); catalogued as rs146897268, COSV55053114; called by muse, mutect2, varscan2
- OR1E2 | c.548T>C p.I183T | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs775251778, COSV50265344; called by muse, mutect2, varscan2
- OR1L8 | c.347T>C p.L116P | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59185740; called by muse, mutect2, varscan2
- OR2A1 | c.287G>A p.C96Y | Missense Mutation (SNP) | VAF 29/524 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.295); catalogued as COSV68822664; called by muse, mutect2
- OR2AE1 | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs200998386; called by muse, mutect2, varscan2
- OR2T34 | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 28/264 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs746667499, COSV60899605, COSV60900803; called by muse, mutect2, varscan2
- OR4C46 | c.328G>T p.G110C | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.401); catalogued as COSV60218358; called by muse, mutect2, varscan2
- OR51B4 | c.896G>T p.S299I | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.439); catalogued as COSV66516768; called by muse, mutect2, varscan2
- OR5A1 | c.455A>G p.Y152C | Missense Mutation (SNP) | VAF 45/355 reads (13%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.983); catalogued as COSV57375717, COSV57376870; called by muse, mutect2, varscan2
- OR5B12 | c.597del p.F199Lfs*13 | Frame Shift Del (DEL) | VAF 8/68 reads (12%) | catalogued as rs747074822; called by mutect2, varscan2
- OR5D13 | c.560T>C p.V187A | Missense Mutation (SNP) | VAF 27/163 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as COSV62332706; called by muse, mutect2, varscan2
- OR7E24 | c.504del p.F168Lfs*12 | Frame Shift Del (DEL) | VAF 7/46 reads (15%) | catalogued as rs1031417078; called by mutect2, pindel, varscan2
- OR8B3 | c.598C>T p.L200F | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.327); catalogued as COSV63541246; called by muse, mutect2, varscan2
- OTULIN | c.958C>T p.P320S | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52504904; called by muse, mutect2
- PADI3 | c.989C>T p.A330V | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV64933932; called by muse, mutect2
- PAFAH1B3 | c.455A>G p.N152S | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as rs767545895, COSV50547361; called by muse, mutect2, varscan2
- PAMR1 | c.1298G>T p.G433V (on ENST00000619888 / NM_001001991.3; = p.G450V on NM_015430.4) | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53509631; called by muse, mutect2, varscan2
- PARP1 | c.1259C>T p.T420M | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.322); catalogued as rs757100394, COSV64689294; called by muse, mutect2, varscan2
- PBX2 | c.1003C>A p.P335T | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV66708680; called by muse, mutect2, varscan2
- PBXIP1 | c.1532G>A p.R511K | Missense Mutation (SNP) | VAF 40/285 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.027); catalogued as COSV63776791; called by muse, mutect2, varscan2
- PCDH10 | c.1408G>A p.V470M | Missense Mutation (SNP) | VAF 21/195 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV52087583; called by muse, mutect2, varscan2
- PCDH7 | c.1418C>T p.A473V | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.75); PolyPhen benign (0.391); catalogued as COSV62336535; called by muse, mutect2, varscan2
- PCDH8 | c.2356del p.A786Pfs*151 | Frame Shift Del (DEL) | VAF 11/65 reads (17%) | catalogued as rs770663005, COSV100131664; called by mutect2, pindel, varscan2
- PCDHA12 | c.652G>A p.G218S | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs782527674, COSV56477886; called by muse, mutect2, varscan2
- PCDHA4 | c.1534G>A p.A512T | Missense Mutation (SNP) | VAF 20/172 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.639); catalogued as rs1348144933, COSV100793269; called by muse, varscan2
- PCDHA8 | c.2197C>T p.R733W | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.058); catalogued as COSV65326379; called by muse, mutect2, varscan2
- PCDHAC1 | c.2637C>A p.S879R | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV53836927; called by muse, mutect2, varscan2
- PCDHB12 | c.1119A>C p.R373S | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.026); catalogued as COSV53393117; called by muse, mutect2, varscan2
- PCDHB13 | c.1214C>T p.T405M | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs1415617021, COSV53393124; called by muse, mutect2, varscan2
- PCDHB9 | c.2170C>T p.R724C | Missense Mutation (SNP) | VAF 35/498 reads (7%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.59); catalogued as COSV53375396; called by muse, mutect2
- PCDHGA11 | c.1975G>A p.V659I | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.474); catalogued as rs771252840, COSV53898850; called by muse, mutect2, varscan2
- PCDHGA9 | c.1978C>T p.L660F | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.33); catalogued as rs752075185, COSV53898838; called by muse, mutect2
- PCDHGB5 | c.2211del p.N738Tfs*26 | Frame Shift Del (DEL) | VAF 29/325 reads (9%) | catalogued as COSV53949594; called by mutect2, pindel
- PCF11 | c.1768A>C p.S590R | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.143); catalogued as COSV100019575, COSV53527525, COSV99036186; called by muse, mutect2, varscan2
- PCNX2 | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs772546873, COSV50782129; called by muse, mutect2, varscan2
- PDE10A | c.607A>T p.I203F | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV63091110; called by muse, mutect2, varscan2
- PFAS | c.3193G>C p.V1065L | Missense Mutation (SNP) | VAF 36/229 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58978467; called by muse, mutect2, varscan2
- PFKFB4 | c.1337G>A p.R446Q | Missense Mutation (SNP) | VAF 10/90 reads (11%) | PolyPhen probably damaging (0.969); catalogued as rs758816952, COSV51679638; called by muse, mutect2, varscan2
- PGS1 | c.1616G>A p.R539H | Missense Mutation (SNP) | VAF 24/167 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs776646232, COSV53143315; called by muse, mutect2, varscan2
- PHF24 | c.677A>G p.Y226C | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV54273014; called by muse, mutect2, varscan2
- PIP4P2 | c.538del p.I180Sfs*21 | Frame Shift Del (DEL) | VAF 18/113 reads (16%) | catalogued as rs1158949501; called by mutect2, pindel, varscan2
- PIP5K1A | c.1151G>A p.G384D (on ENST00000368888 / NM_001135638.2; = p.G371D on NM_003557.3) | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV62957347; called by muse, mutect2, varscan2
- PITPNM3 | c.1270C>T p.R424C | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1174190065, COSV52592901; called by muse, mutect2, varscan2
- PKD1L1 | c.7361C>T p.T2454I | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.269); catalogued as rs536060017, COSV51841316; called by muse, mutect2
- PKLR | c.1376C>T p.A459V | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.221); catalogued as CM961128, COSV61360371; called by muse, mutect2, varscan2
- PKP1 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99825068; called by muse, mutect2
- PLA2G7 | c.814C>T p.H272Y | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201187668, COSV51258426; called by muse, mutect2, varscan2
- PLAAT3 | c.338G>A p.C113Y | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1281809643, COSV60310915; called by muse, mutect2, varscan2
- PLBD1 | c.1426C>T p.R476C | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755656884, COSV53691777; called by muse, mutect2
- PLEC | c.13309C>T p.R4437W (on ENST00000322810 / NM_201380.4; = p.R4327W on NM_000445.5) | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs782022985, COSV59603750; called by muse, mutect2, varscan2
- PLGRKT | c.227del p.K76Rfs*12 | Frame Shift Del (DEL) | VAF 10/78 reads (13%) | catalogued as rs765091847; called by mutect2, varscan2
- PLK4 | c.1388C>T p.P463L | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV54636304; called by muse, mutect2, varscan2
- PLOD3 | c.2158G>A p.E720K | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768681053, COSV56181291; called by muse, mutect2
- PLP1 | c.347C>T p.T116M | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.971); catalogued as rs749278720, CM962400, COSV58275616; called by muse, mutect2, varscan2
- PLXNB2 | c.415G>A p.G139R | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.911); catalogued as COSV63780090, COSV63780141; called by muse, mutect2
- PMM1 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 11/179 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.068); catalogued as COSV53447090, COSV53449623; called by muse, mutect2
- POLR3A | c.1860G>T p.K620N | Missense Mutation (SNP) | VAF 22/179 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.447); catalogued as COSV64930235; called by muse, mutect2, varscan2
- POLR3A | c.1748T>G p.L583R | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV64930237; called by muse, mutect2, varscan2
- PORCN | c.1139G>A p.R380Q (on ENST00000326194 / NM_203475.3; = p.R369Q on NM_022825.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as rs782631909, COSV58225508; called by muse, mutect2, varscan2
- PPA1 | c.838G>A p.V280M | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs753250934, COSV64683402; called by mutect2, varscan2
- PPARGC1A | c.668C>T p.T223I | Missense Mutation (SNP) | VAF 38/207 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as COSV53524475; called by muse, mutect2, varscan2
- PPP2R2D | c.229T>C p.Y77H | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.595); catalogued as COSV70778606; called by muse, mutect2, varscan2
- PPP3R2 | c.181G>A p.V61I | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756326986, COSV62450318; called by muse, mutect2, varscan2
- PRG4 | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV66622930; called by muse, mutect2, varscan2
- PRKCE | c.1841A>G p.D614G | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60312595; called by muse, mutect2, varscan2
- PRKDC | c.10840T>C p.Y3614H | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV58042825; called by muse, mutect2, varscan2
- PRMT1 | c.1099G>A p.D367N | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.783); catalogued as COSV54917572; called by muse, mutect2, varscan2
- PROS1 | c.1162G>A p.V388M | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV67774170; called by muse, mutect2
- PRPF40B | c.99del p.M34Cfs*29 (on ENST00000380281; = p.M28Cfs*29 on NM_012272.3) | Frame Shift Del (DEL) | VAF 26/190 reads (14%) | catalogued as COSV56058435; called by mutect2, pindel, varscan2
- PRRT2 | c.344G>A p.S115N | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.001); catalogued as rs758952009, COSV54881360; called by muse, mutect2
- PRSS54 | c.209G>A p.G70D | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54688948; called by muse, mutect2
- PRUNE2 | c.8523del p.D2842Mfs*55 | Frame Shift Del (DEL) | VAF 37/309 reads (12%) | catalogued as rs1564467302, COSV56314316; called by mutect2, pindel, varscan2
- PRUNE2 | c.49C>T p.R17C | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs373655912; called by muse, mutect2, varscan2
- PSD | c.593del p.G198Afs*19 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | catalogued as COSV99194092; called by mutect2, pindel
- PSMB6 | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54512630; called by muse, mutect2, varscan2
- PSMC3IP | c.634G>A p.V212I (on ENST00000393795 / NM_016556.4; = p.V200I on NM_013290.6) | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.119); catalogued as rs149230650; called by muse, mutect2, varscan2
- PSMD13 | c.1126A>G p.T376A | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.906); catalogued as COSV61500331; called by muse, mutect2, varscan2
- PTGDS | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs767866230, COSV56399345; called by muse, mutect2, varscan2
- PTPN21 | c.2545del p.I849Lfs*9 | Frame Shift Del (DEL) | VAF 16/99 reads (16%) | catalogued as rs778292578; called by mutect2, varscan2
- PTPN21 | c.1924G>A p.G642R | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1292576530, COSV60845759; called by muse, mutect2, varscan2
- PTPN5 | c.179del p.P60Lfs*65 | Frame Shift Del (DEL) | VAF 30/269 reads (11%) | catalogued as COSV100659978; called by mutect2, pindel, varscan2
- PTX4 | c.1191del p.G398Efs*57 (on ENST00000447419 / NM_001328608.2; = p.G393Efs*57 on NM_001013658.1) | Frame Shift Del (DEL) | VAF 9/66 reads (14%) | catalogued as rs772722517, COSV99560265; called by pindel, varscan2
- PXYLP1 | c.826G>A p.G276R | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.01); catalogued as rs545979594, COSV53888623; called by muse, mutect2, varscan2
- QSER1 | c.5090del p.N1697Mfs*4 (on ENST00000399302; = p.N1826Mfs*4 on NM_001076786.3) | Frame Shift Del (DEL) | VAF 7/47 reads (15%) | catalogued as rs754588466; called by mutect2, varscan2
- RAB11FIP1 | c.1937A>C p.N646T | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.311); catalogued as COSV54758211; called by muse, mutect2
- RAB3IL1 | c.854C>T p.T285M | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs548685284, COSV57116775; called by muse, mutect2
- RABEPK | c.40A>G p.R14G | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as COSV52334095; called by muse, mutect2
- RAD51AP1 | c.208del p.R70Dfs*21 (on ENST00000228843 / NM_001130862.2; = p.R70Gfs*4 on NM_006479.5) | Frame Shift Del (DEL) | VAF 8/50 reads (16%) | catalogued as rs745353960; called by mutect2, pindel, varscan2
- RAD54L | c.1634G>A p.G545D | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58438888; called by muse, mutect2, varscan2
- RAD54L | c.1708A>G p.M570V | Missense Mutation (SNP) | VAF 27/180 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV58438892; called by muse, mutect2, varscan2
- RAI1 | c.632A>G p.Q211R | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV55389071; called by muse, mutect2, varscan2
- RALGDS | c.2407C>T p.R803C | Missense Mutation (SNP) | VAF 20/193 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64425629; called by muse, mutect2, varscan2
- RAP1GAP | c.1759G>A p.G587R | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs946717941, COSV51568598, COSV51577229; called by muse, mutect2, varscan2
- RAPH1 | c.1261C>T p.R421* (on ENST00000319170 / NM_213589.3; = p.R473* on NM_203365.4) | Nonsense Mutation (SNP) | VAF 24/205 reads (12%) | catalogued as rs541215148, COSV57350825; called by muse, mutect2, varscan2
- RASL11B | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.414); catalogued as COSV50534750; called by muse, mutect2, varscan2
- RBM43 | c.406del p.I136Sfs*4 | Frame Shift Del (DEL) | VAF 36/151 reads (24%) | catalogued as rs142934811, CD1212851; called by mutect2, varscan2
- RBSN | c.362T>C p.V121A | Missense Mutation (SNP) | VAF 39/320 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.366); catalogued as COSV53791568; called by muse, mutect2, varscan2
- RBX1 | c.217G>T p.G73* | Nonsense Mutation (SNP) | VAF 6/48 reads (13%) | catalogued as COSV53429604; called by muse, mutect2, varscan2
- RCC1L | c.685G>A p.D229N | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as rs782710435; called by muse, mutect2, varscan2
- REV1 | c.133T>C p.S45P | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV51481784; called by muse, mutect2, varscan2
- RFX4 | c.1057G>A p.V353M (on ENST00000392842 / NM_213594.3; = p.V259M on NM_032491.6) | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as COSV99985568; called by muse, mutect2, varscan2
- RGS12 | c.2980C>T p.R994W | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs772197757, COSV58748711; called by muse, mutect2, varscan2
- RGS12 | c.3534del p.K1178Nfs*32 | Frame Shift Del (DEL) | VAF 16/82 reads (20%) | catalogued as rs753542639, COSV58750063; called by mutect2, varscan2
- RGS9 | c.1336C>A p.P446T | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52223091; called by muse, mutect2, varscan2
- RHOJ | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as COSV57456574, COSV57457254; called by muse, mutect2, varscan2
- RIPK4 | c.1730C>T p.S577L (on ENST00000352483; = p.S529L on NM_020639.3) | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.024); catalogued as rs766787567, COSV60185281; called by muse, mutect2, varscan2
- RNF145 | c.766C>T p.R256C (on ENST00000424310 / NM_001199383.2; = p.R284C on NM_144726.2) | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs139327325; called by mutect2, varscan2
- RNF17 | c.965A>G p.Q322R | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.058); catalogued as COSV55033990; called by muse, mutect2, varscan2
- RNF34 | c.164C>T p.T55M | Missense Mutation (SNP) | VAF 22/266 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs61760895, COSV63441915; called by muse, mutect2
- ROBO1 | c.4662G>T p.Q1554H | Missense Mutation (SNP) | VAF 94/586 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV71391703; called by muse, mutect2, varscan2
- RP1L1 | c.3682A>G p.T1228A | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as COSV66751713; called by muse, mutect2, varscan2
- RP1L1 | c.3166G>A p.A1056T | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as COSV66751716; called by muse, mutect2, varscan2
- RPGRIP1 | c.3437A>G p.Y1146C | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV52844704; called by muse, mutect2, varscan2
- RPGRIP1L | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 20/240 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs886042345, COSV50902701; ClinVar: uncertain significance; called by muse, mutect2
- RPS10-NUDT3 | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.988); catalogued as rs758507410, COSV58242007; called by mutect2, varscan2
- RPS4Y1 | c.337C>T p.R113C | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.563); catalogued as rs779925430, COSV51710885; called by muse, mutect2, varscan2
- RPS6KA6 | c.1825G>T p.G609* | Nonsense Mutation (SNP) | VAF 29/131 reads (22%) | catalogued as COSV53116167; called by muse, mutect2, varscan2
- RSL1D1 | c.1437del p.K479Nfs*40 | Frame Shift Del (DEL) | VAF 48/311 reads (15%) | catalogued as rs770576841; called by mutect2, pindel, varscan2
- RTN4RL1 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as rs1326974609, COSV58674416; called by muse, mutect2, varscan2
- RTP1 | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.987); catalogued as rs376513971, COSV56617667; called by muse, mutect2, varscan2
- RUSC2 | c.955G>A p.A319T | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as rs758569757, COSV63427619; called by muse, mutect2, varscan2
- RYR3 | c.6613G>A p.V2205M | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs1385551494, CM142578, COSV66777921; ClinVar: uncertain significance; called by muse, mutect2
- RYR3 | c.7610C>T p.T2537M (on ENST00000389232; = p.T2538M on NM_001036.6) | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs576237958, COSV66777931; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SALL3 | c.3295G>T p.A1099S | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV73305759; called by muse, mutect2, varscan2
- SAMD4B | c.1210G>A p.A404T | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs769283919, COSV58750111, COSV58752695; called by muse, mutect2, varscan2
- SAMSN1 | c.187G>T p.G63* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | catalogued as COSV53467479; called by muse, mutect2, varscan2
- SARS1 | c.46C>A p.P16T | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52319536; called by muse, mutect2, varscan2
- SCARF1 | c.1841G>A p.R614Q | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs780488988, COSV53957358; called by muse, mutect2, varscan2
- SCN3B | c.386A>G p.E129G | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.057); catalogued as COSV54798141; called by muse, mutect2, varscan2
- SCN5A | c.4151G>A p.C1384Y (on ENST00000333535 / NM_198056.3; = p.C1383Y on NM_000335.5) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1321911273, COSV61115886; called by muse, mutect2, varscan2
- SCYL1 | c.849+2T>C p.X283_splice | Splice Site (SNP) | VAF 8/75 reads (11%) | catalogued as COSV54210526; called by muse, mutect2, varscan2
- SEC14L3 | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs1488655384, COSV53177889; called by muse, mutect2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 14/72 reads (19%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SEMA3C | c.1607G>A p.G536D | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54841288; called by muse, mutect2, varscan2
- SEPTIN3 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV52170692; called by muse, mutect2, varscan2
- SERP2 | c.16C>T p.R6W | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs780531159, COSV64851504; called by muse, mutect2, varscan2
- SETBP1 | c.2180G>A p.R727Q | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56313088, COSV56313647; called by muse, mutect2, varscan2
- SETDB1 | c.3728G>A p.R1243H | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54977297; called by muse, mutect2, varscan2
- SFSWAP | c.1682C>T p.S561L | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as rs761916541, COSV55519432; called by muse, mutect2, varscan2
- SGSM3 | c.755G>A p.R252H | Missense Mutation (SNP) | VAF 19/154 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.118); catalogued as rs199978228, COSV50651193; called by muse, mutect2, varscan2
- SH3RF2 | c.1744C>A p.L582I | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV63037098; called by muse, mutect2, varscan2
- SH3YL1 | c.361A>G p.T121A | Missense Mutation (SNP) | VAF 17/195 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as rs755947134, COSV62155424; called by muse, mutect2
- SHANK2 | c.3916T>A p.S1306T | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.161); catalogued as COSV53585772; called by muse, mutect2, varscan2
- SIAH3 | c.94G>A p.G32R | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV68551350; called by muse, mutect2, varscan2
- SIK3 | c.2116dup p.Q707Afs*3 (on ENST00000445177 / NM_001366686.2; = p.Q665Afs*3 on NM_025164.6 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 23/200 reads (12%) | catalogued as rs1344077789; called by mutect2, pindel, varscan2
- SIRPG | c.1027C>A p.L343I | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.011); catalogued as COSV53805916; called by muse, mutect2, varscan2
- SLC10A7 | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV53880294; called by muse, mutect2, varscan2
- SLC12A9 | c.1674dup p.L559Afs*76 | Frame Shift Ins (INS) | VAF 10/62 reads (16%) | catalogued as rs747309463; called by mutect2, varscan2
- SLC13A5 | c.634A>G p.I212V | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV53421639; called by muse, mutect2, varscan2
- SLC14A1 | c.725G>T p.G242V | Missense Mutation (SNP) | VAF 22/181 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV58930784, COSV58931349; called by muse, mutect2, varscan2
- SLC24A2 | c.954T>G p.D318E | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV53857496; called by muse, mutect2
- SLC25A51 | c.92T>C p.M31T | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.021); catalogued as COSV54252221; called by muse, mutect2, varscan2
- SLC26A11 | c.163G>A p.G55S | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58338422; called by muse, mutect2, varscan2
- SLC26A5 | c.2087C>A p.P696H | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as COSV59698129; called by muse, mutect2, varscan2
- SLC2A3 | c.590T>C p.L197P | Missense Mutation (SNP) | VAF 21/155 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV50000424; called by muse, mutect2, varscan2
- SLC34A2 | c.1588G>A p.V530I | Missense Mutation (SNP) | VAF 29/222 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs752794996, COSV65940658; called by muse, mutect2, varscan2
- SLC3A2 | c.899del p.K300Rfs*31 | Frame Shift Del (DEL) | VAF 14/94 reads (15%) | catalogued as rs760089491; called by mutect2, varscan2
- SLC47A2 | c.1681G>A p.A561T | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs113234335, COSV51565603; called by muse, mutect2
- SLC4A2 | c.2020C>T p.P674S | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV59655683; called by muse, mutect2
- SLC7A13 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.735); catalogued as COSV52532510; called by muse, mutect2, varscan2
- SLC7A6 | c.1270-1G>A p.X424_splice | Splice Site (SNP) | VAF 27/249 reads (11%) | catalogued as COSV50449861; called by muse, mutect2, varscan2
- SLC8A1 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs150791349; called by mutect2, varscan2
- SLCO5A1 | c.374C>T p.T125M | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as rs1386415293, COSV52653692; called by muse, mutect2, varscan2
- SLIT3 | c.1611G>A p.L537= | Splice Region (SNP) | VAF 8/114 reads (7%) | catalogued as COSV60592735; called by muse, mutect2
- SMAP2 | c.827C>T p.T276M | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as rs202167503, COSV65531225; called by muse, mutect2, varscan2
- SMARCAD1 | c.1394T>A p.I465N | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV62772910; called by muse, mutect2
- SMARCB1 | c.796G>A p.A266T (on ENST00000263121; = p.A312T on NM_003073.5) | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs749348930, COSV54093406, COSV54101879; called by muse, mutect2, varscan2
- SMG5 | c.1948A>G p.M650V | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs373014142; called by muse, mutect2, varscan2
- SMG6 | c.2506C>T p.R836W | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.417); catalogued as rs149940409; called by muse, mutect2
- SMPD4 | c.326G>A p.C109Y | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0.071); catalogued as COSV100302297; called by muse, mutect2, varscan2
- SMUG1 | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs547497060, COSV54538723; called by muse, mutect2, varscan2
- SNAP25 | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as rs1481810638, COSV54770405, COSV54774288; called by muse, mutect2, varscan2
- SNX22 | c.446G>A p.C149Y | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV55519547; called by muse, mutect2, varscan2
- SOBP | c.1298G>A p.G433D | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57995766; called by muse, mutect2, varscan2
- SP2 | c.527C>A p.P176H | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV65063352; called by muse, varscan2
- SPAG6 | c.721G>A p.V241M | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.736); catalogued as rs751730219, COSV57617998; called by muse, mutect2, varscan2
- SPAG9 | c.1645del p.R549Gfs*28 (on ENST00000262013 / NM_001130528.3; = p.R535Gfs*28 on NM_003971.6) | Frame Shift Del (DEL) | VAF 11/60 reads (18%) | catalogued as rs371303534; called by mutect2, varscan2
- SPATA31D1 | c.599T>C p.L200P | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.204); catalogued as COSV61192769; called by muse, mutect2, varscan2
- SPESP1 | c.1007del p.N336Ifs*12 | Frame Shift Del (DEL) | VAF 9/98 reads (9%) | catalogued as COSV52994315; called by mutect2, pindel, varscan2
- SPIB | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.997); catalogued as rs773054847, COSV54529578, COSV54531549; called by muse, mutect2, varscan2
- SPOCK1 | c.142G>A p.V48I | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as rs1432941348, COSV56436869; called by muse, mutect2
- SPOP | c.904G>A p.A302T | Missense Mutation (SNP) | VAF 29/164 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.661); catalogued as COSV61652823; called by muse, mutect2, varscan2
- SPRTN | c.44G>T p.W15L | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.093); catalogued as COSV50477531; called by muse, mutect2, varscan2
- SPTBN2 | c.4917C>A p.D1639E | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.026); catalogued as COSV59446666; called by muse, mutect2, varscan2
- SPTBN4 | c.5754G>T p.Q1918H | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.036); catalogued as COSV58943488; called by muse, mutect2, varscan2
- SRBD1 | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 41/261 reads (16%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.043); catalogued as COSV55395816; called by muse, mutect2, varscan2
- SREBF2 | c.2293del p.L765Wfs*13 | Frame Shift Del (DEL) | VAF 16/118 reads (14%) | catalogued as COSV63331442; called by mutect2, pindel, varscan2
- SRP72 | c.1384C>T p.R462W | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs771523590, COSV61377671; called by mutect2, varscan2
- SRRM2 | c.5357G>A p.R1786Q | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs769997548, COSV57068173; called by muse, mutect2, varscan2
- SRRT | c.1507C>T p.R503C | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53815008; called by muse, mutect2, varscan2
- SSB | c.578del p.N193Mfs*13 | Frame Shift Del (DEL) | VAF 10/63 reads (16%) | catalogued as rs753297385; called by mutect2, varscan2
- ST3GAL1 | c.14G>A p.R5Q | Missense Mutation (SNP) | VAF 13/122 reads (11%) | PolyPhen benign (0.009); catalogued as rs145602093; called by muse, mutect2, varscan2
- ST8SIA4 | c.785A>G p.H262R | Missense Mutation (SNP) | VAF 9/99 reads (9%) | PolyPhen benign (0.017); catalogued as COSV51506084, COSV99185165; called by muse, mutect2
- ST8SIA4 | c.4C>T p.R2C | Missense Mutation (SNP) | VAF 14/62 reads (23%) | PolyPhen probably damaging (0.973); catalogued as rs1412320214, COSV51506099; called by muse, mutect2, varscan2
- STAT6 | c.2444dup p.G816Rfs*139 | Frame Shift Ins (INS) | VAF 7/75 reads (9%) | catalogued as rs749654830; called by mutect2, pindel
- STIL | c.3363del p.K1121Nfs*3 | Frame Shift Del (DEL) | VAF 21/188 reads (11%) | catalogued as COSV99680901; called by mutect2, varscan2
- STXBP4 | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as rs769987070, COSV54840286; called by muse, mutect2, varscan2
- SV2A | c.374dup p.S127Efs*2 | Frame Shift Ins (INS) | VAF 20/156 reads (13%) | catalogued as rs1167154522; called by mutect2, varscan2
- SVIL | c.434C>A p.A145D | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.219); catalogued as COSV63439782; called by muse, mutect2
- SYNE1 | c.8266del p.I2756* (on ENST00000367255 / NM_182961.4; = p.I2763* on NM_033071.3) | Frame Shift Del (DEL) | VAF 15/132 reads (11%) | catalogued as COSV54961656; called by mutect2, pindel, varscan2
- SYNE2 | c.19249del p.L6417Wfs*94 | Frame Shift Del (DEL) | VAF 10/94 reads (11%) | catalogued as COSV59942610; called by mutect2, pindel
- SYT3 | c.1379C>T p.A460V | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV58895472; called by muse, mutect2
- TASOR | c.2810T>C p.V937A (on ENST00000355628 / NM_001365636.2; = p.V561A on NM_015224.3) | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.073); catalogued as COSV62926790; called by muse, mutect2, varscan2
- TAX1BP1 | c.1760A>T p.Y587F | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.02); catalogued as COSV55290505, COSV55297544; called by muse, mutect2
- TBC1D16 | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as rs370476450; called by muse, mutect2, varscan2
- TBC1D2 | c.493G>A p.V165I | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as rs772793838, COSV59782246; called by muse, mutect2, varscan2
- TBC1D23 | c.1947del p.K649Nfs*18 (on ENST00000394144 / NM_001199198.3; = p.K634Nfs*18 on NM_018309.5) | Frame Shift Del (DEL) | VAF 11/64 reads (17%) | catalogued as rs747637295, COSV61367528; called by mutect2, varscan2
- TBCEL | c.889C>T p.R297* | Nonsense Mutation (SNP) | VAF 8/42 reads (19%) | catalogued as rs377427847; called by muse, mutect2
- TBL1Y | c.1203C>A p.S401R | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.094); catalogued as COSV60732400; called by muse, mutect2, varscan2
- TBX20 | c.959A>G p.E320G | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV68782588; called by muse, varscan2
- TBX5 | c.119C>T p.S40L | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as COSV59858488; called by muse, mutect2, varscan2
- TCF20 | c.5826del p.L1943Cfs*118 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | catalogued as rs756457255; called by pindel, varscan2
- TCF21 | c.222G>T p.Q74H | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV52817724; called by muse, mutect2, varscan2
- TECRL | c.293A>C p.K98T | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV67086185; called by muse, mutect2, varscan2
- TEX15 | c.7421G>T p.G2474V (on ENST00000256246; = p.G2857V on NM_001350162.2) | Missense Mutation (SNP) | VAF 26/181 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV56341560, COSV56349288; called by muse, mutect2, varscan2
- TFAP2D | c.404G>C p.G135A | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as COSV50408458; called by muse, mutect2, varscan2
- TGFB3 | c.1080+1G>A p.X360_splice | Splice Site (SNP) | VAF 17/91 reads (19%) | catalogued as COSV53168929; called by muse, mutect2, varscan2
- THSD7A | c.2896G>A p.V966M | Missense Mutation (SNP) | VAF 21/173 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.059); catalogued as COSV70260303; called by muse, mutect2, varscan2
- THUMPD2 | c.860C>T p.A287V | Missense Mutation (SNP) | VAF 23/223 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs373324639; called by muse, mutect2, varscan2
- TIAM1 | c.4619G>A p.R1540Q | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs751890515, COSV54537698; called by muse, mutect2, varscan2
- TICAM1 | c.335C>T p.S112L | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as rs749264598, COSV50229434; called by muse, mutect2, varscan2
- TIE1 | c.1039T>C p.S347P | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV65248471; called by muse, mutect2, varscan2
- TMEM11 | c.266G>A p.G89D | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1200110980, COSV58312760; called by muse, mutect2, varscan2
- TMEM132A | c.1480del p.L494Cfs*82 (on ENST00000453848 / NM_178031.3; = p.L495Cfs*82 on NM_017870.4) | Frame Shift Del (DEL) | VAF 5/33 reads (15%) | catalogued as COSV50001098; called by mutect2, pindel
- TMEM132D | c.1864G>A p.A622T | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs777948878, COSV67158727; called by muse, varscan2
- TMEM208 | c.226C>T p.R76* | Nonsense Mutation (SNP) | VAF 8/42 reads (19%) | catalogued as rs200755290; called by muse, mutect2, varscan2
- TMEM255B | c.969del p.Y324Tfs*9 | Frame Shift Del (DEL) | VAF 25/248 reads (10%) | catalogued as COSV100944145; called by mutect2, pindel, varscan2
- TMEM41A | c.467del p.F156Sfs*5 | Frame Shift Del (DEL) | VAF 19/134 reads (14%) | catalogued as rs758476632; called by mutect2, varscan2
- TNKS2 | c.1213C>T p.H405Y | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65414665; called by muse, mutect2, varscan2
- TNPO2 | c.926C>T p.S309L | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.096); catalogued as rs1215459207, COSV63507532; called by muse, mutect2
- TNS1 | c.1837C>A p.P613T | Missense Mutation (SNP) | VAF 13/169 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as COSV50690653; called by muse, mutect2
- TNS4 | c.1367G>A p.R456Q | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs143122913; called by muse, mutect2, varscan2
- TOE1 | c.775C>T p.R259W | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.96); catalogued as rs201425549, COSV59149227; called by muse, mutect2, varscan2
- TOR1A | c.787A>G p.I263V | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.13); catalogued as COSV52212319; called by muse, mutect2, varscan2
- TOR1AIP2 | c.922C>A p.L308M | Missense Mutation (SNP) | VAF 24/168 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV62625554; called by muse, mutect2, varscan2
- TPP2 | c.112del p.V38Cfs*39 | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | catalogued as rs1368797323; called by mutect2, varscan2
- TPP2 | c.3627A>C p.K1209N | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV65750988; called by muse, mutect2, varscan2
- TRIM35 | c.862C>T p.Q288* | Nonsense Mutation (SNP) | VAF 4/56 reads (7%) | catalogued as COSV59522295; called by muse, mutect2
- TRIM4 | c.1270G>A p.A424T | Missense Mutation (SNP) | VAF 36/299 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.025); catalogued as COSV62468351; called by muse, mutect2, varscan2
- TRIM41 | c.1601G>A p.R534H | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs755074419, COSV59317455, COSV59320656; called by muse, mutect2, varscan2
- TRIM56 | c.1868G>A p.R623Q | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs1024062078, COSV60157182; called by muse, mutect2, varscan2
- TRIM68 | c.1252G>T p.V418F | Missense Mutation (SNP) | VAF 7/113 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.377); catalogued as COSV56167491; called by muse, mutect2
- TRIP12 | c.4417C>A p.L1473I | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV52259212; called by muse, mutect2, varscan2
- TRMT44 | c.1238T>C p.F413S | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV67663337, COSV67664098; called by muse, mutect2, varscan2
- TRPM1 | c.4265G>A p.R1422H | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.006); catalogued as rs748246121, COSV56630508; called by muse, mutect2, varscan2
- TRPM6 | c.5390C>T p.P1797L | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.066); catalogued as rs772763308, COSV62502957; called by muse, mutect2, varscan2
- TSGA10IP | c.1174C>T p.R392W | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs779591922, COSV73245200, COSV73245257; called by muse, mutect2, varscan2
- TSPAN12 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.234); catalogued as COSV56078508; called by muse, mutect2, varscan2
- TSR1 | c.2405dup p.M803Hfs*26 | Frame Shift Ins (INS) | VAF 19/202 reads (9%) | catalogued as rs752002924; called by mutect2, pindel, varscan2
- TSSK2 | c.416G>A p.C139Y | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52816120; called by muse, mutect2, varscan2
- TTBK1 | c.2054A>G p.Y685C | Missense Mutation (SNP) | VAF 39/247 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.712); catalogued as COSV52488124; called by muse, mutect2, varscan2
- TTC38 | c.798C>T p.G266= | Splice Region (SNP) | VAF 7/68 reads (10%) | catalogued as rs749513954, COSV66843580; called by mutect2, varscan2
- TTI1 | c.3087-1G>A p.X1029_splice | Splice Site (SNP) | VAF 3/48 reads (6%) | catalogued as rs886066923; called by muse, mutect2
- TTN | c.83860A>G p.T27954A (on ENST00000591111; = p.T20530A on NM_003319.4) | Missense Mutation (SNP) | VAF 12/69 reads (17%) | PolyPhen benign (0.225); catalogued as COSV59888587; called by muse, mutect2, varscan2
- TTN | c.21586A>G p.K7196E (on ENST00000591111; = p.K6269E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/202 reads (12%) | PolyPhen benign (0.083); catalogued as COSV59888701; called by muse, mutect2, varscan2
- TTYH2 | c.749C>T p.A250V | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV53908566; called by muse, mutect2, varscan2
- TUBA3E | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.013); catalogued as rs780831143, COSV56058185; called by muse, mutect2, varscan2
- TUFT1 | c.604A>G p.S202G | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as rs1306566937, COSV61947866; called by muse, mutect2, varscan2
- UGT1A6 | c.1555A>G p.K519E | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as rs553499095, COSV59381895; ClinVar: uncertain significance; called by muse, mutect2
- UHRF1BP1 | c.3996del p.I1333Sfs*20 | Frame Shift Del (DEL) | VAF 8/75 reads (11%) | catalogued as COSV51954201; called by mutect2, pindel, varscan2
- UPF2 | c.3099A>T p.E1033D | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs1367060563, COSV62658267; called by muse, mutect2
- UROC1 | c.920del p.K307Rfs*77 | Frame Shift Del (DEL) | VAF 32/236 reads (14%) | catalogued as rs754361807; called by mutect2, varscan2
- USP19 | c.1700C>A p.P567H | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60044916; called by muse, mutect2
- USP26 | c.1836del p.G613Afs*26 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | catalogued as rs749830910; called by mutect2, varscan2
- VCAN | c.4094A>G p.H1365R | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.243); catalogued as rs773919986, COSV54096963; called by muse, mutect2, varscan2
440 further variants in this file (169 protein-altering or splice-affecting, 249 silent, 22 other) are not listed here.
